Somatic mutation profile of tumor specimen TCGA-AM-5821-01A (aliquot TCGA-AM-5821-01A-01D-1650-10) from TCGA case TCGA-AM-5821, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 68.2 years (24,903 days).
Specimen TCGA-AM-5821-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 07491ff3-ccfa-4346-83bc-bfb461784469.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AM-5821-10A (Blood Derived Normal), aliquot TCGA-AM-5821-10A-01D-1650-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/41db6e94-0ecf-4a1a-9443-e571f7dfae0a

The open-access MAF lists 1,462 somatic variants for this specimen: 1,113 protein-altering or splice-affecting, 321 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 837, Silent 321, Frame Shift Del 183, Frame Shift Ins 43, Nonsense Mutation 27, Intron 14, Splice Site 13, Splice Region 7, RNA 6, 3'UTR 4, In Frame Del 3, 3'Flank 2.

Variants (750 of 1,462; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACADVL | c.1316del p.G439Vfs*5 | Frame Shift Del (DEL) | VAF 24/87 reads (28%) | catalogued as rs748077880; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ATM | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 54/148 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs138398778, CM0910483, COSV53723836, COSV53775938; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 49/137 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FGD1 | c.527del p.P176Hfs*39 | Frame Shift Del (DEL) | VAF 28/44 reads (64%) | catalogued as rs756586058; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- LARS2 | c.*276C>T | 3'UTR (SNP) | VAF 39/95 reads (41%) | catalogued as rs398123036, CM132510, COSV55527677; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYH7 | c.5530G>A p.E1844K | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs730880821, COSV62519291; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- NIPBL | c.1808del p.K603Sfs*11 | Frame Shift Del (DEL) | VAF 30/116 reads (26%) | catalogued as rs727503767; ClinVar: pathogenic; called by mutect2, varscan2
- PCDH19 | c.1091del p.P364Rfs*4 | Frame Shift Del (DEL) | VAF 14/43 reads (33%) | catalogued as rs758946412, CD134966; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 44/136 reads (32%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RPGRIP1L | c.1945C>T p.R649* | Nonsense Mutation (SNP) | VAF 10/86 reads (12%) | catalogued as rs751477523, CM1212113, COSV50905127; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 12/71 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A1BG | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.267); catalogued as rs375725715; called by muse, mutect2, varscan2
- AADACL2 | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 62/176 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100735625, COSV62929925; called by muse, mutect2, varscan2
- AARS2 | c.2607del p.T871Lfs*13 | Frame Shift Del (DEL) | VAF 7/18 reads (39%) | catalogued as rs771808127, COSV55113098; called by mutect2, varscan2
- ABCA13 | c.12656C>T p.T4219M | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.555); catalogued as rs1348315361, COSV68946856; called by muse, mutect2, varscan2
- ABCB9 | c.1024G>A p.V342M | Missense Mutation (SNP) | VAF 82/175 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.706); catalogued as rs146512146, COSV54891872; called by muse, mutect2, varscan2
- ABCC2 | c.778C>T p.R260W | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.724); catalogued as rs370287805; called by muse, mutect2, varscan2
- ABCC5 | c.758C>G p.A253G | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV55590255, COSV55595468; called by muse, mutect2, varscan2
- ABCC9 | c.4633G>A p.V1545M | Missense Mutation (SNP) | VAF 79/153 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV53971738; called by muse, mutect2, varscan2
- ABCD1 | c.731C>T p.S244L | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.7); PolyPhen benign (0.099); catalogued as rs1557052505, COSV54384796; called by muse, mutect2, varscan2
- ABHD18 | c.893A>G p.Q298R (on ENST00000398965 / NM_001039717.2; = p.Q205R on NM_025097.2 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/167 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.022); catalogued as COSV66293857; called by muse, mutect2, varscan2
- ABI3 | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.55); PolyPhen benign (0.089); catalogued as rs778504447, COSV56800106; called by muse, mutect2, varscan2
- AC005324.2 | c.907C>A p.L303M | Missense Mutation (SNP) | VAF 20/161 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60886781; called by muse, mutect2, varscan2
- AC011462.1 | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.319); catalogued as rs536540966, COSV54195750; called by muse, mutect2, varscan2
- ACKR3 | c.914T>C p.L305P | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99799581; called by muse, mutect2, varscan2
- ACP3 | c.542T>C p.L181P | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV60486115; called by muse, mutect2, varscan2
- ACSL1 | c.967G>A p.A323T | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1228732572, COSV55662728; called by muse, mutect2, varscan2
- ACSM2A | c.1212del p.G405Afs*16 (on ENST00000219054; = p.G326Afs*16 on NM_001308169.2) | Frame Shift Del (DEL) | VAF 30/90 reads (33%) | catalogued as rs755296455; called by mutect2, varscan2
- ACTN1 | c.2171T>G p.I724S | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV51991923; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 40/70 reads (57%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADA2 | c.596A>C p.N199T | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV52831471; called by muse, mutect2, varscan2
- ADAMTS15 | c.1651G>A p.G551R | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755197416, COSV54505593; called by muse, mutect2, varscan2
- ADCY10 | c.1316C>T p.A439V | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as rs752239529, COSV63240926; called by muse, mutect2, varscan2
- ADCY9 | c.709G>A p.V237I | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.88); catalogued as rs766756605, COSV53575298; called by muse, mutect2, varscan2
- ADGRG4 | c.5645C>T p.S1882F | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54963948; called by muse, mutect2, varscan2
- AGAP1 | c.1822G>A p.E608K (on ENST00000304032 / NM_001037131.3; = p.E555K on NM_014914.5) | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.187); catalogued as rs370536569; called by muse, mutect2, varscan2
- AGAP6 | c.1480C>T p.R494* (on ENST00000374056 / NM_001365867.1; = p.R517* on NM_001077665.2) | Nonsense Mutation (SNP) | VAF 40/123 reads (33%) | catalogued as rs782767193, COSV65017686; called by muse, mutect2, varscan2
- AGFG1 | c.56A>C p.D19A | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV100028812; called by muse, mutect2
- AGPAT1 | c.340A>C p.M114L | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.348); catalogued as COSV100421642; called by muse, mutect2
- AGTPBP1 | c.724G>A p.D242N | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.998); catalogued as COSV100429789, COSV61272827; called by muse, varscan2
- AK5 | c.1543G>A p.A515T (on ENST00000354567 / NM_174858.3; = p.A489T on NM_012093.4) | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.081); catalogued as rs747870282, COSV100643360, COSV60972063; called by muse, mutect2, varscan2
- AK8 | c.36del p.E13Rfs*14 | Frame Shift Del (DEL) | VAF 39/102 reads (38%) | catalogued as rs757477831; called by mutect2, pindel, varscan2
- AKAP6 | c.3545T>C p.V1182A | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV55214109; called by muse, mutect2, varscan2
- ALDH6A1 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as rs374367200; called by muse, mutect2, varscan2
- ALDOA | c.607C>T p.R203C (on ENST00000642816 / NM_001243177.4; = p.R149C on NM_184041.5) | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as rs772548302, COSV57632759; called by muse, mutect2, varscan2
- ALPK1 | c.2654C>T p.A885V | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs1253598326, COSV51585117; called by muse, mutect2, varscan2
- ALPK2 | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 50/342 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as rs746498471, COSV64492089; called by muse, mutect2, varscan2
- ALPK3 | c.4213C>T p.R1405* | Nonsense Mutation (SNP) | VAF 57/157 reads (36%) | catalogued as rs1344615174, COSV51939552; called by muse, mutect2, varscan2
- ALX4 | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs200419726, COSV61326530; called by mutect2, varscan2
- AMBRA1 | c.2420G>T p.R807M (on ENST00000458649 / NM_001367468.1; = p.R717M on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.87); catalogued as COSV54054082; called by muse, mutect2, varscan2
- AMER3 | c.758T>G p.V253G | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV100366590; called by mutect2, varscan2
- AMIGO1 | c.608C>A p.P203H | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV63990390; called by muse, mutect2, varscan2
- AMPH | c.263A>C p.D88A | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV57742223; called by muse, mutect2, varscan2
- ANGEL1 | c.623C>A p.P208H | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.915); catalogued as COSV99200402; called by muse, mutect2, varscan2
- ANKRD49 | c.208del p.M70Wfs*32 | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | catalogued as rs753570186; called by mutect2, varscan2
- ANKS4B | c.226G>A p.G76S | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV61139249; called by muse, mutect2, varscan2
- ANKS6 | c.1694C>T p.S565F | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62052480; called by muse, mutect2, varscan2
- ANLN | c.2712T>C p.A904= | Splice Region (SNP) | VAF 44/167 reads (26%) | catalogued as COSV99732351; called by muse, mutect2, varscan2
- ANOS1 | c.1944G>T p.K648N | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as rs1333397224, COSV52920113; called by muse, mutect2, varscan2
- AOC3 | c.1346C>T p.S449L | Missense Mutation (SNP) | VAF 58/172 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1200194786, COSV53826651; called by muse, mutect2, varscan2
- APBB1IP | c.1244G>A p.R415Q | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1216651320, COSV66132510; called by muse, mutect2, varscan2
- APOBR | c.2817G>T p.E939D (on ENST00000431282; = p.E948D on NM_018690.4) | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs376544257, COSV60490885; called by muse, mutect2, varscan2
- ARFGAP3 | c.669del p.G224Afs*32 | Frame Shift Del (DEL) | VAF 97/330 reads (29%) | catalogued as rs1436718702, COSV54312627; called by mutect2, varscan2
- ARHGAP10 | c.1625T>C p.L542P | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1309427358, COSV60599510; called by muse, mutect2, varscan2
- ARHGEF6 | c.836C>A p.T279N | Missense Mutation (SNP) | VAF 73/205 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV51690799; called by muse, mutect2, varscan2
- ARHGEF9 | c.161A>G p.E54G | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV99491838; called by mutect2, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 16/68 reads (24%) | catalogued as COSV61389445; called by mutect2, pindel, varscan2
- ARL6IP4 | c.985T>C p.W329R (on ENST00000315580 / NM_018694.3; = p.W310R on NM_016638.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV54900857; called by muse, mutect2, varscan2
- ARSK | c.887C>T p.A296V | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV101187499; called by muse, mutect2, varscan2
- ASTN2 | c.1133C>T p.S378L | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.885); catalogued as rs747307846, COSV57809694; called by muse, mutect2, varscan2
- ATAD2 | c.1528G>A p.E510K | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99784724; called by muse, mutect2, varscan2
- ATAD2 | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 56/168 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs755251005, COSV54879444; called by muse, varscan2
- ATAT1 | c.863A>C p.E288A | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV99527980; called by muse, mutect2, varscan2
- ATG9B | c.1681G>A p.A561T | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0.014); catalogued as COSV52496541; called by mutect2, varscan2
- ATM | c.6923C>T p.A2308V | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs876658454, COSV53764712, COSV99589731; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP10B | c.2155G>A p.A719T | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59151962; called by muse, mutect2, varscan2
- ATP13A5 | c.232A>G p.T78A | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.498); catalogued as COSV60869389; called by muse, mutect2, varscan2
- ATP1A2 | c.1088A>G p.E363G | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV63403780; called by muse, mutect2, varscan2
- ATP2C2 | c.758A>G p.Q253R | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (1); PolyPhen probably damaging (0.998); catalogued as rs368931246; called by mutect2, varscan2
- ATP6V0D2 | c.842T>G p.V281G | Missense Mutation (SNP) | VAF 132/342 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.185); catalogued as COSV53415006; called by muse, mutect2, varscan2
- ATP7A | c.2710G>A p.A904T | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs1427317043, COSV58455245; ClinVar: uncertain significance; called by muse, varscan2
- ATRX | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 36/178 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as CM980196, COSV64870776; called by muse, mutect2, varscan2
- B4GALT6 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52703301; called by muse, mutect2, varscan2
- B4GALT7 | c.482T>C p.M161T | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50353291; called by muse, mutect2, varscan2
- BAZ2B | c.5899A>C p.T1967P | Missense Mutation (SNP) | VAF 38/242 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); catalogued as COSV58600968, COSV58601631; called by muse, mutect2, varscan2
- BBS4 | c.1248+2T>C p.X416_splice | Splice Site (SNP) | VAF 33/117 reads (28%) | catalogued as COSV51437958; called by muse, mutect2, varscan2
- BBS9 | c.2389A>C p.S797R (on ENST00000242067 / NM_001348036.1; = p.S757R on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.386); catalogued as COSV54168240; called by muse, mutect2, varscan2
- BCL2L13 | c.622T>C p.S208P | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV58225829; called by muse, mutect2, varscan2
- BCO2 | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0.38); catalogued as COSV63063431; called by muse, mutect2, varscan2
- BCR | c.3269G>A p.R1090H | Missense Mutation (SNP) | VAF 75/214 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100006556; called by muse, mutect2, varscan2
- BGN | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368783683, COSV59036896; called by muse, mutect2, varscan2
- BMP1 | c.2170A>G p.S724G | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV60479485; called by muse, mutect2, varscan2
- BMP2 | c.226C>A p.P76T | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66577890; called by muse, mutect2, varscan2
- BMP3 | c.605T>A p.I202N | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99261708; called by muse, mutect2, varscan2
- BMPR2 | c.1606C>T p.R536C | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as rs773416598, COSV101001507; called by muse, varscan2
- BOC | c.2285A>G p.D762G | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56350904; called by muse, mutect2, varscan2
- BRD4 | c.2496G>T p.Q832H | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as COSV54586265; called by muse, mutect2, varscan2
- BRINP3 | c.1370G>A p.R457H | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs201165374, COSV66513018, COSV66537847; called by muse, mutect2, varscan2
- C10orf90 | c.1675T>C p.C559R | Missense Mutation (SNP) | VAF 44/135 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.022); catalogued as COSV52955490; called by muse, mutect2, varscan2
- C12orf4 | c.818G>A p.S273N | Missense Mutation (SNP) | VAF 58/437 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99712748; called by muse, mutect2, varscan2
- C1QTNF3 | c.179G>A p.G60D | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51468644; called by muse, mutect2
- C1orf105 | c.443G>T p.R148M | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62959316; called by muse, mutect2, varscan2
- C21orf58 | c.422G>T p.R141M | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV52449757; called by muse, mutect2, varscan2
- C4B | c.3650T>C p.L1217P | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV101312237; called by muse, mutect2, varscan2
- C5orf38 | c.169C>A p.P57T | Missense Mutation (SNP) | VAF 43/86 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.393); catalogued as COSV57414046; called by muse, mutect2, varscan2
- C8orf76 | c.902T>C p.M301T | Missense Mutation (SNP) | VAF 44/143 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as rs559914198, COSV52690578; called by muse, mutect2, varscan2
- CA5A | c.781G>A p.A261T | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.175); catalogued as COSV59240754; called by muse, mutect2, varscan2
- CACHD1 | c.2731G>A p.D911N | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0.083); catalogued as COSV99262342; called by muse, mutect2, varscan2
- CACNB2 | c.1127A>G p.D376G (on ENST00000324631 / NM_201596.3; = p.D321G on NM_000724.4) | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56624669; called by muse, mutect2, varscan2
- CAPRIN1 | c.1054C>G p.P352A | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1185300715, COSV58219884; called by muse, mutect2, varscan2
- CARNS1 | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 26/188 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as rs1007612294, COSV57130071; called by muse, mutect2, varscan2
- CASP7 | c.375del p.A126Lfs*17 | Frame Shift Del (DEL) | VAF 13/60 reads (22%) | catalogued as rs1247046723, COSV61881818; called by mutect2*, varscan2
- CASZ1 | c.637T>C p.S213P | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as COSV59735622; called by muse, mutect2, varscan2
- CATSPERB | c.971T>C p.L324P | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56426576; called by muse, mutect2, varscan2
- CBFA2T3 | c.1500G>T p.Q500H | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV51927070; called by muse, mutect2, varscan2
- CCDC158 | c.1271G>A p.R424Q | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.806); catalogued as rs1329795418, COSV101187423, COSV66355999; called by muse, mutect2, varscan2
- CCDC30 | c.1151A>C p.K384T (on ENST00000340612; = p.K341T on NM_001080850.3) | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100501358; called by muse, mutect2, varscan2
- CCDC82 | c.527A>G p.D176G | Missense Mutation (SNP) | VAF 230/730 reads (32%) | SIFT tolerated (0.61); PolyPhen benign (0.015); catalogued as COSV99567327; called by muse, varscan2
- CCNB3 | c.2774T>A p.V925D | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as COSV52070078; called by muse, mutect2
- CCNB3 | c.2915G>A p.G972E | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT tolerated (0.95); PolyPhen benign (0.001); catalogued as COSV52073840; called by muse, mutect2, varscan2
- CCR7 | c.431T>C p.M144T | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV99878706; called by muse, mutect2, varscan2
- CD200R1 | c.745A>G p.I249V (on ENST00000471858 / NM_170780.3; = p.I272V on NM_138806.4) | Missense Mutation (SNP) | VAF 56/330 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.359); catalogued as COSV99867275; called by muse, mutect2, varscan2
- CD207 | c.386G>A p.S129N | Missense Mutation (SNP) | VAF 104/340 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs1553400349, COSV69652096; called by muse, mutect2, varscan2
- CD300LG | c.613C>A p.P205T | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV53223831; called by muse, mutect2, varscan2
- CD37 | c.458G>T p.C153F | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60544341; called by muse, mutect2, varscan2
- CD4 | c.589A>G p.I197V | Missense Mutation (SNP) | VAF 44/205 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.257); catalogued as COSV50590723; called by muse, mutect2, varscan2
- CD55 | c.385T>C p.C129R | Missense Mutation (SNP) | VAF 11/126 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100132442; called by muse, mutect2
- CD93 | c.361del p.E121Rfs*79 | Frame Shift Del (DEL) | VAF 11/36 reads (31%) | catalogued as rs762805003; called by mutect2, pindel, varscan2
- CDCA8 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV100523597; called by muse, mutect2, varscan2
- CDH23 | c.2886G>T p.Q962H | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as COSV99821110; called by muse, mutect2
- CDHR3 | c.536A>G p.K179R | Missense Mutation (SNP) | VAF 82/632 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as COSV100488382; called by muse, mutect2, varscan2
- CDHR4 | c.495G>A p.Q165= | Splice Region (SNP) | VAF 14/102 reads (14%) | catalogued as COSV58526183; called by muse, mutect2, varscan2
- CDK2AP1 | c.203C>T p.A68V | Missense Mutation (SNP) | VAF 21/190 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.438); catalogued as COSV55542588; called by muse, mutect2, varscan2
- CDK4 | c.409G>A p.V137I | Missense Mutation (SNP) | VAF 24/195 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.061); catalogued as rs150281463, COSV56985308; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CELSR2 | c.5817G>T p.E1939D | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.018); catalogued as COSV54771891; called by muse, mutect2, varscan2
- CEP120 | c.2103G>T p.K701N | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100071131; called by muse, mutect2, varscan2
- CEP170 | c.3346C>T p.L1116F | Missense Mutation (SNP) | VAF 105/308 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.874); catalogued as rs1361597838, COSV100317114; called by muse, mutect2, varscan2
- CEP170B | c.1933del p.Q645Rfs*179 (on ENST00000453495; = p.Q574Rfs*179 on NM_015005.3) | Frame Shift Del (DEL) | VAF 7/20 reads (35%) | catalogued as rs1431118175; called by mutect2, pindel
- CEP192 | c.3184C>T p.R1062C | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs781491201, COSV58064373; called by muse, mutect2, varscan2
- CEP290 | c.4247G>A p.R1416H | Missense Mutation (SNP) | VAF 64/113 reads (57%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs374582514; called by muse, mutect2, varscan2
- CEP83 | c.1944C>A p.S648R | Missense Mutation (SNP) | VAF 24/192 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.642); catalogued as COSV51575423; called by muse, mutect2, varscan2
- CFAP20DC | c.505A>T p.I169F (on ENST00000482387 / NM_001351530.2; = p.I44F on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/159 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs745547707, COSV55920325; called by muse, mutect2, varscan2
- CFAP94 | c.454A>C p.T152P (on ENST00000320267 / NM_001352064.2; = p.T158P on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); catalogued as COSV57232259; called by muse, mutect2, varscan2
- CFC1 | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 76/474 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.081); catalogued as rs772626752, COSV99383460; called by muse, mutect2, varscan2
- CHD1 | c.4378G>C p.E1460Q | Missense Mutation (SNP) | VAF 38/270 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.671); catalogued as COSV52340332; called by muse, varscan2
- CHD1L | c.2123A>C p.D708A | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV63613974; called by muse, mutect2, varscan2
- CHD4 | c.1815A>C p.K605N (on ENST00000357008 / NM_001363606.2; = p.K618N on NM_001273.5) | Missense Mutation (SNP) | VAF 67/451 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.548); catalogued as COSV100538087; called by muse, mutect2, varscan2
- CHD8 | c.7112dup p.N2371Kfs*2 (on ENST00000646647 / NM_001170629.2; = p.N2092Kfs*2 on NM_020920.4) | Frame Shift Ins (INS) | VAF 34/166 reads (20%) | catalogued as rs751094013; called by mutect2, varscan2
- CHD9 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV68298203; called by muse, mutect2, varscan2
- CHRD | c.2821G>T p.E941* | Nonsense Mutation (SNP) | VAF 45/126 reads (36%) | catalogued as COSV52607948; called by muse, mutect2, varscan2
- CHST8 | c.877G>A p.A293T | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.541); catalogued as rs747129678, COSV52858942; called by mutect2, varscan2
- CIAO3 | c.824_826del p.G275del | In Frame Del (DEL) | VAF 6/31 reads (19%) | catalogued as rs748580275; called by mutect2, pindel
- CIDEC | c.311A>G p.D104G | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as COSV61061657; called by muse, mutect2, varscan2
- CILP2 | c.1442C>A p.A481D | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV52275029; called by muse, mutect2, varscan2
- CKAP5 | c.4939A>G p.I1647V (on ENST00000529230 / NM_001008938.4; = p.I1587V on NM_014756.3) | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as COSV56367825; called by muse, mutect2, varscan2
- CLUAP1 | c.52T>C p.Y18H | Missense Mutation (SNP) | VAF 43/272 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs770554988, COSV100489678; called by muse, mutect2, varscan2
- CLUH | c.1324dup p.D442Gfs*99 (on ENST00000435359; = p.D480Gfs*99 on NM_015229.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 14/81 reads (17%) | catalogued as rs752224729; called by mutect2, varscan2
- CNDP1 | c.859T>C p.S287P | Missense Mutation (SNP) | VAF 79/251 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.697); catalogued as COSV62593942; called by muse, mutect2, varscan2
- CNP | c.650A>G p.K217R | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV66368102; called by muse, mutect2, varscan2
- CNTLN | c.3941C>T p.A1314V | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs773093657, COSV52099655; called by mutect2, varscan2
- CNTRL | c.2414G>A p.R805H | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200179809, COSV53046884; called by muse, varscan2
- COG2 | c.1781G>A p.R594Q | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758756274, COSV64186430; called by muse, mutect2, varscan2
- COL11A1 | c.3768A>C p.E1256D | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.956); catalogued as COSV100616633; called by muse, varscan2
- COL27A1 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as rs770533328, COSV61921095; called by muse, mutect2
- COL4A3 | c.3755C>T p.A1252V | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs761179248, COSV59257746; called by muse, mutect2, varscan2
- COL4A4 | c.4105C>A p.P1369T | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.999); catalogued as COSV61632241; called by muse, mutect2, varscan2
- COL6A2 | c.1744G>A p.G582S | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750533442, COSV56005191; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COPA | c.2416A>C p.T806P | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV54102176, COSV54102442; called by muse, mutect2, varscan2
- COPZ1 | c.500C>T p.A167V | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50432377; called by muse, mutect2, varscan2
- COX5A | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as rs774638701, COSV59279449; called by muse, mutect2, varscan2
- CP | c.1051T>C p.F351L | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV52829296; called by muse, mutect2, varscan2
- CPD | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56710764, COSV56712919; called by muse, mutect2, varscan2
- CPEB4 | c.1049G>A p.R350H | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV54169384; called by muse, mutect2, varscan2
- CPO | c.104A>C p.K35T | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.051); catalogued as COSV55939850; called by muse, mutect2, varscan2
- CPSF1 | c.701G>A p.R234Q | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV62940238; called by muse, mutect2, varscan2
- CPXCR1 | c.518T>C p.V173A | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.395); catalogued as COSV52162319; called by muse, mutect2, varscan2
- CPXM2 | c.913C>T p.R305W | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs372846460; called by muse, mutect2, varscan2
- CREB3L3 | c.739del p.I247Sfs*57 | Frame Shift Del (DEL) | VAF 5/47 reads (11%) | catalogued as CX115357; called by mutect2, pindel, varscan2
- CREB3L4 | c.211C>T p.L71F | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.459); catalogued as COSV55210181; called by muse, mutect2, varscan2
- CREB5 | c.1150C>T p.R384W (on ENST00000357727 / NM_182898.4; = p.R377W on NM_004904.3) | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63219842; called by muse, mutect2, varscan2
- CREBBP | c.1229C>T p.A410V | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV52124152; called by muse, mutect2, varscan2
- CRIM1 | c.2326A>G p.I776V | Missense Mutation (SNP) | VAF 24/233 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54864279; called by muse, varscan2
- CRYBG2 | c.1178del p.K393Rfs*16 | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | catalogued as rs747248693; called by mutect2, varscan2
- CSGALNACT2 | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs763376840, COSV65675610; called by muse, mutect2, varscan2
- CSMD3 | c.10460A>C p.K3487T (on ENST00000297405 / NM_001363185.1; = p.K3318T on NM_052900.3) | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as rs995865371, COSV52183546; called by muse, mutect2, varscan2
- CSMD3 | c.9518G>A p.C3173Y (on ENST00000297405 / NM_001363185.1; = p.C3004Y on NM_052900.3) | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99835055; called by muse, mutect2, varscan2
- CSMD3 | c.3184A>G p.T1062A (on ENST00000297405 / NM_001363185.1; = p.T958A on NM_052900.3) | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.491); catalogued as rs1275626732, COSV52126752, COSV99849922; called by muse, mutect2, varscan2
- CSNK1G2 | c.883C>T p.R295W | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as rs1325933418, COSV99729922; called by muse, mutect2, varscan2
- CSPG4 | c.1328del p.G443Afs*16 | Frame Shift Del (DEL) | VAF 12/87 reads (14%) | catalogued as rs772622628; called by mutect2, varscan2
- CSTF2 | c.1498C>T p.Q500* | Nonsense Mutation (SNP) | VAF 77/164 reads (47%) | catalogued as COSV65895292; called by muse, mutect2, varscan2
- CTC1 | c.427A>G p.S143G | Missense Mutation (SNP) | VAF 41/205 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100236461; called by muse, varscan2
- CTNNB1 | c.125del p.T42Kfs*5 | Frame Shift Del (DEL) | VAF 44/143 reads (31%) | catalogued as COSV62689063, COSV62693534, COSV62711661; called by mutect2, pindel, varscan2
- CTNNB1 | c.768T>G p.I256M | Missense Mutation (SNP) | VAF 109/376 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV62700610; called by muse, mutect2, varscan2
- CTU2 | c.359G>A p.G120D | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV56337360; called by mutect2, varscan2
- CUEDC2 | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 149/473 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.236); catalogued as COSV50045999, COSV99192723; called by muse, mutect2, varscan2
- CYB5R3 | c.536C>T p.A179V | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs201232518, CM980558, COSV61545561; called by muse, mutect2, varscan2
- CYP11A1 | c.325C>A p.L109I | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV51432135; called by muse, mutect2, varscan2
- CYP1B1 | c.769G>A p.V257I | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs769699570, COSV53191459; called by muse, mutect2, varscan2
- CYP26B1 | c.1280G>A p.G427D | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.463); catalogued as COSV50011823; called by muse, mutect2, varscan2
- CYP7A1 | c.1058C>T p.S353L | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs778961537, COSV56963611; called by muse, mutect2, varscan2
- CYRIA | c.218A>C p.Q73P | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV100838400; called by muse, varscan2
- DAB2IP | c.1024A>G p.M342V (on ENST00000408936; = p.M314V on NM_032552.3) | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.46); catalogued as rs1025468666, COSV52259451; called by muse, mutect2, varscan2
- DACH2 | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64169115; called by muse, mutect2, varscan2
- DACH2 | c.1044C>G p.N348K | Missense Mutation (SNP) | VAF 74/204 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs889147525, COSV64169128; called by muse, mutect2, varscan2
- DAG1 | c.1704C>A p.S568R | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0.065); catalogued as COSV58184452; called by muse, mutect2, varscan2
- DCAF8L1 | c.718A>G p.I240V | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as COSV101491466; called by muse, mutect2, varscan2
- DCC | c.2510T>C p.V837A | Missense Mutation (SNP) | VAF 73/218 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV59103145; called by muse, mutect2, varscan2
- DCPS | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs371676072; called by mutect2, varscan2
- DDX17 | c.1552G>A p.A518T | Missense Mutation (SNP) | VAF 19/198 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53247727; called by muse, mutect2, varscan2
- DENND4B | c.3398G>A p.R1133H | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs763865336, COSV63409179; called by muse, mutect2, varscan2
- DENND4B | c.2987C>A p.P996H | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.21); catalogued as COSV100768699; called by muse, mutect2, varscan2
- DENND4B | c.788T>G p.L263R | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100768701; called by muse, mutect2, varscan2
- DIAPH3 | c.1636G>A p.A546T (on ENST00000400324 / NM_001042517.2; = p.A283T on NM_030932.3) | Missense Mutation (SNP) | VAF 77/256 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as rs762809019, COSV57370698; called by muse, varscan2
- DIP2A | c.1221C>A p.D407E | Missense Mutation (SNP) | VAF 127/456 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.71); catalogued as COSV59477554; called by muse, mutect2, varscan2
- DIP2C | c.4555G>A p.V1519M | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.422); catalogued as rs755001458, COSV55158459; called by muse, mutect2, varscan2
- DIS3L2 | c.1727G>A p.R576H | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.12); catalogued as rs200386096; ClinVar: uncertain significance; called by muse, varscan2
- DISP3 | c.3994T>C p.Y1332H | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99608696; called by muse, mutect2, varscan2
- DLEC1 | c.3786-1G>T p.X1262_splice | Splice Site (SNP) | VAF 10/73 reads (14%) | catalogued as COSV100341944; called by muse, varscan2
- DMPK | c.260T>C p.V87A | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1285618495, COSV52178330; called by muse, mutect2, varscan2
- DNAH12 | c.176A>G p.D59G | Missense Mutation (SNP) | VAF 69/250 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV60857021; called by muse, mutect2, varscan2
- DNAH2 | c.7225C>A p.Q2409K | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.59); PolyPhen benign (0.009); catalogued as COSV66718993; called by muse, mutect2, varscan2
- DNAH3 | c.10010C>T p.T3337M | Missense Mutation (SNP) | VAF 51/147 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.247); catalogued as rs530510705, COSV54505745; called by muse, mutect2, varscan2
- DNM3 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62458050; called by muse, mutect2, varscan2
- DNMBP | c.1939C>A p.L647M | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV60625228; called by muse, mutect2, varscan2
- DOCK2 | c.3914C>T p.A1305V | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as rs370316549; called by muse, mutect2, varscan2
- DOCK7 | c.3587T>C p.V1196A (on ENST00000635253 / NM_001367561.1; = p.V1165A on NM_033407.3) | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as COSV52005739; called by muse, mutect2, varscan2
- DOCK8 | c.3430G>A p.A1144T | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as rs1030455029, COSV66621040, COSV66624321; called by muse, mutect2, varscan2
- DRD1 | c.175A>C p.T59P | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67104605; called by muse, mutect2, varscan2
- DSCAML1 | c.5417G>A p.S1806N (on ENST00000321322; = p.S1746N on NM_020693.4) | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as COSV58390833; called by muse, mutect2, varscan2
- DSPP | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.188); catalogued as rs773490979, COSV56808618; called by muse, mutect2, varscan2
- DST | c.2329G>T p.E777* (on ENST00000361203 / NM_001374722.1; = p.E451* on NM_001723.6) | Nonsense Mutation (SNP) | VAF 46/131 reads (35%) | catalogued as COSV55014940; called by muse, mutect2, varscan2
- DUOX2 | c.3929T>C p.L1310P | Missense Mutation (SNP) | VAF 54/177 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.333); catalogued as COSV101199778; called by muse, mutect2, varscan2
- DUSP5 | c.91T>C p.Y31H | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100851899; called by muse, mutect2, varscan2
- DYNC1H1 | c.10337G>A p.R3446H | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.677); catalogued as rs779245575, COSV64137023; called by muse, mutect2, varscan2
- E2F4 | c.953G>A p.S318N | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.441); catalogued as rs201338753; called by muse, varscan2
- ECE1 | c.1285C>T p.L429F | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.652); catalogued as COSV99941852; called by muse, mutect2, varscan2
- ECEL1 | c.1445G>A p.G482D | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.86); PolyPhen benign (0.007); catalogued as rs1415594665, COSV100458741; called by muse, mutect2, varscan2
- EDNRA | c.871A>G p.R291G | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.159); catalogued as COSV100163392; called by muse, varscan2
- EEF1AKNMT | c.1472T>G p.L491R (on ENST00000361735 / NM_015935.5; = p.L405R on NM_014955.3) | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.277); catalogued as COSV100675873; called by muse, mutect2
- EFHC1 | c.576A>T p.V192= | Splice Region (SNP) | VAF 6/36 reads (17%) | catalogued as COSV100932042; called by muse, varscan2
- EGFR | c.1124C>T p.A375V | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.494); catalogued as COSV99291226; called by muse, mutect2, varscan2
- EHHADH | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV51630204; called by muse, mutect2, varscan2
- ELAVL4 | c.848G>A p.S283N | Missense Mutation (SNP) | VAF 28/188 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.009); catalogued as rs1236212349, COSV63915880; called by muse, varscan2
- ELF4 | c.983G>A p.R328Q | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.075); catalogued as rs764880211, COSV100257576, COSV57452994; called by muse, mutect2, varscan2
- ELOA2 | c.743T>C p.L248S | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV55299196; called by muse, mutect2, varscan2
- EML4 | c.596C>A p.P199H | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.155); catalogued as COSV59305962; called by muse, mutect2, varscan2
- ENAH | c.739C>T p.R247* | Nonsense Mutation (SNP) | VAF 31/267 reads (12%) | catalogued as COSV52867982; called by muse, mutect2, varscan2
- EPHB4 | c.1576A>C p.T526P | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100639510; called by mutect2, varscan2
- EPM2AIP1 | c.502C>T p.R168* | Nonsense Mutation (SNP) | VAF 22/81 reads (27%) | catalogued as COSV51618120; called by muse, mutect2, varscan2
- ERCC2 | c.1781C>A p.A594D | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67270887; called by muse, mutect2, varscan2
- ERN2 | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs140769667; called by mutect2, varscan2
- ERVW-1 | c.424A>G p.T142A | Missense Mutation (SNP) | VAF 77/272 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as COSV101423841; called by muse, mutect2, varscan2
- ESYT3 | c.2288G>A p.R763H | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as rs369262503; called by muse, mutect2, varscan2
- ETV1 | c.985T>C p.Y329H | Missense Mutation (SNP) | VAF 46/344 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV54142745; called by muse, mutect2, varscan2
- ETV6 | c.1142G>A p.G381E | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56765875; called by muse, mutect2, varscan2
- EVC | c.1420C>A p.L474M | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53832747; called by muse, mutect2, varscan2
- EVI5 | c.648del p.F216Lfs*15 | Frame Shift Del (DEL) | VAF 13/86 reads (15%) | catalogued as rs1453325274; called by mutect2, pindel, varscan2
- EXTL3 | c.998C>A p.P333Q | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.137); catalogued as COSV55038041; called by muse, mutect2, varscan2
- F13A1 | c.889G>A p.V297I | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as rs199564311, COSV53553068; ClinVar: uncertain significance; called by mutect2, varscan2
- F8 | c.2935T>C p.W979R | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as CD094295, COSV100811551; called by muse, mutect2, varscan2
- FAAP100 | c.700A>G p.T234A | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1177583227, COSV100585383; called by mutect2, varscan2
- FAM107B | c.343A>G p.K115E (on ENST00000378458 / NM_001320737.1; = p.K290E on NM_031453.3) | Missense Mutation (SNP) | VAF 17/196 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99473988; called by muse, mutect2
- FAM160A2 | c.883C>T p.P295S | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.264); catalogued as rs1362370588, COSV99792108; called by muse, mutect2, varscan2
- FAM186B | c.1060A>G p.M354V | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV57721593; called by muse, mutect2, varscan2
- FASN | c.3916G>A p.A1306T | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs751832838, COSV60754865; called by muse, mutect2, varscan2
- FAT4 | c.5660G>A p.G1887D | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.999); catalogued as rs1289355950, COSV58685811; called by muse, mutect2, varscan2
- FBXW11 | c.449T>C p.V150A | Missense Mutation (SNP) | VAF 88/262 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV51609210; called by muse, mutect2, varscan2
- FCN1 | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.238); catalogued as rs756646348, COSV65662353; called by muse, mutect2, varscan2
- FCRL4 | c.817C>T p.H273Y | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.047); catalogued as COSV54862320; called by muse, mutect2, varscan2
- FCRL5 | c.797C>A p.P266H | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.335); catalogued as COSV100708963; called by muse, mutect2, varscan2
- FER1L6 | c.4582G>A p.A1528T | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV101205883, COSV67552653; called by muse, mutect2
- FEZ1 | c.695T>C p.L232P | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99630672; called by muse, mutect2, varscan2
- FGD5 | c.3908G>A p.R1303Q | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.964); catalogued as rs537125427, COSV53253877; called by muse, mutect2
- FGFR2 | c.2210G>T p.R737M | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV60647140; called by muse, mutect2, varscan2
- FGFR2 | c.2209A>G p.R737G | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV60647169; called by muse, mutect2, varscan2
- FILIP1L | c.35C>G p.A12G | Missense Mutation (SNP) | VAF 101/340 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV58769057; called by muse, varscan2
- FLRT2 | c.1967A>G p.E656G | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.435); catalogued as COSV58141616; called by muse, mutect2, varscan2
- FLT4 | c.3122G>A p.R1041Q | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM001159, CM032231, COSV56108343, COSV56115160; called by muse, mutect2, varscan2
- FLVCR2 | c.590T>C p.M197T | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as rs1347864878, COSV53162349; called by muse, mutect2, varscan2
- FMN2 | c.1763C>T p.T588M | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as rs773346283, COSV100145172, COSV60428548; called by muse, mutect2, varscan2
- FMNL1 | c.2570A>G p.Y857C | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as rs1329541247, COSV58956959; called by muse, mutect2, varscan2
- FMNL3 | c.1522C>A p.P508T | Missense Mutation (SNP) | VAF 67/127 reads (53%) | SIFT tolerated (0.33); PolyPhen benign (0.022); catalogued as COSV53301974, COSV99526941; called by muse, mutect2, varscan2
- FMO1 | c.842A>G p.E281G | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1432588819, COSV61445795; called by muse, varscan2
- FMO5 | c.983T>G p.F328C | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54206729; called by muse, mutect2, varscan2
- FOXL2 | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.508); catalogued as COSV57727105; called by muse, mutect2, varscan2
- FREM2 | c.1591A>G p.N531D | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99748882; called by muse, varscan2
- FREM2 | c.2723A>C p.K908T | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.023); catalogued as COSV54837958; called by muse, mutect2, varscan2
- FRG2B | c.731C>T p.A244V | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.136); catalogued as COSV101423521; called by muse, varscan2
- FRMD4A | c.254A>G p.D85G | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV52723330; called by muse, varscan2
- FRMD5 | c.1150C>T p.R384W | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs150697882; called by muse, mutect2, varscan2
- FRMPD4 | c.1974C>A p.F658L | Missense Mutation (SNP) | VAF 61/215 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV66211373, COSV66214999; called by muse, mutect2, varscan2
- FRYL | c.1777C>T p.R593C | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV99976974; called by muse, mutect2, varscan2
- FSIP2 | c.20436A>C p.E6812D | Missense Mutation (SNP) | VAF 84/368 reads (23%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.878); catalogued as COSV58086112; called by muse, mutect2, varscan2
- FUCA2 | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 94/287 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.615); catalogued as rs543674576, COSV50020126; called by muse, varscan2
- FURIN | c.1223C>T p.A408V | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.247); catalogued as COSV51578654, COSV99184685; called by muse, mutect2, varscan2
- FZD1 | c.1358C>T p.A453V | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV55310522; called by muse, mutect2, varscan2
- GABBR1 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV63542535; called by muse, mutect2, varscan2
- GABBR2 | c.2221G>A p.V741M | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as rs370955037, COSV99410364; called by muse, mutect2, varscan2
- GABRA3 | c.1184C>A p.T395N | Missense Mutation (SNP) | VAF 150/922 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.062); catalogued as COSV64798909; called by muse, mutect2, varscan2
- GABRQ | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 50/113 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868935588, COSV64782056; called by muse, mutect2, varscan2
- GAL3ST1 | c.1159G>A p.A387T | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.084); catalogued as COSV100143092; called by muse, mutect2, varscan2
- GALNT5 | c.2432G>T p.S811I | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); catalogued as COSV99375211; called by muse, mutect2, varscan2
- GALNT7 | c.1934C>T p.T645M | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs755005166, COSV53929982; called by muse, mutect2, varscan2
- GALNT9 | c.1104G>T p.E368D (on ENST00000328957 / NM_001122636.2; = p.E2D on NM_021808.3) | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as COSV61098821; called by muse, mutect2, varscan2
- GALNTL5 | c.994dup p.W332Lfs*32 | Frame Shift Ins (INS) | VAF 17/127 reads (13%) | catalogued as rs1305363588; called by mutect2, pindel, varscan2
- GAN | c.1374-1G>T p.X458_splice | Splice Site (SNP) | VAF 165/458 reads (36%) | catalogued as COSV73720900; called by muse, mutect2, varscan2
- GAP43 | c.676G>T p.G226C | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.807); catalogued as COSV59344314; called by muse, mutect2, varscan2
- GARRE1 | c.2858C>A p.T953K | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.759); catalogued as COSV55098048, COSV55099313; called by muse, mutect2, varscan2
- GAS2L1 | c.1033dup p.H345Pfs*12 | Frame Shift Ins (INS) | VAF 12/30 reads (40%) | catalogued as rs1013370449; called by mutect2, varscan2
- GASK1B | c.639del p.S214Pfs*3 | Frame Shift Del (DEL) | VAF 10/106 reads (9%) | catalogued as COSV99647600; called by mutect2, pindel
- GBP6 | c.1760del p.N587Mfs*18 | Frame Shift Del (DEL) | VAF 17/123 reads (14%) | catalogued as rs1557544730; called by mutect2, pindel, varscan2
- GCLM | c.635T>C p.L212S | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64687055; called by muse, mutect2, varscan2
- GCN1 | c.3916G>A p.A1306T | Missense Mutation (SNP) | VAF 57/115 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.845); catalogued as rs981778548, COSV56107837; called by muse, mutect2, varscan2
- GCN1 | c.3050G>T p.R1017M | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56107843; called by muse, mutect2, varscan2
- GDF6 | c.31G>A p.V11I | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV54622932; called by muse, mutect2, varscan2
- GEMIN8 | c.616G>A p.G206R | Missense Mutation (SNP) | VAF 32/189 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60550146; called by muse, mutect2, varscan2
- GGT6 | c.1432G>A p.A478T (on ENST00000574154 / NM_001122890.3; = p.A446T on NM_153338.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs762142364, COSV54592825; called by muse, mutect2, varscan2
- GIGYF1 | c.2105G>A p.R702H | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); catalogued as rs748843458, COSV99309426; called by muse, mutect2, varscan2
- GLB1 | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56563737; called by muse, mutect2, varscan2
- GLG1 | c.2524G>A p.A842T | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV52667120; called by muse, mutect2, varscan2
- GLI2 | c.1432C>T p.R478W (on ENST00000361492 / NM_001374353.1; = p.R495W on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58042124; called by muse, mutect2, varscan2
- GLI2 | c.4288T>G p.Y1430D (on ENST00000361492 / NM_001374353.1; = p.Y1447D on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100083274; called by mutect2, varscan2
- GLP2R | c.301G>T p.D101Y | Missense Mutation (SNP) | VAF 111/341 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52324942, COSV52330559; called by muse, mutect2, varscan2
- GMEB2 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.877); catalogued as COSV56607147, COSV99823410; called by muse, mutect2, varscan2
- GNB4 | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); catalogued as COSV51709588; called by muse, mutect2, varscan2
- GOLGA3 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as rs770869313, COSV52631434; called by muse, mutect2, varscan2
- GORASP1 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.69); catalogued as rs147603751; called by muse, mutect2, varscan2
- GORASP2 | c.1177G>A p.A393T | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.009); catalogued as rs778067597, COSV52201913; called by muse, mutect2, varscan2
- GPR142 | c.1265G>A p.R422Q | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs772556540, COSV59519366; called by muse, mutect2, varscan2
- GPR183 | c.188T>A p.I63N | Missense Mutation (SNP) | VAF 72/251 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV63118043; called by muse, varscan2
- GPR37 | c.1202G>A p.R401H | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0.37); catalogued as rs369674783; called by muse, mutect2, varscan2
- GPR55 | c.311G>A p.S104N | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.75); PolyPhen benign (0.095); catalogued as rs1020158762, COSV67407725; called by muse, mutect2, varscan2
- GPR6 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51570914; called by muse, mutect2, varscan2
- GPRASP1 | c.2772C>A p.C924* | Nonsense Mutation (SNP) | VAF 10/128 reads (8%) | catalogued as COSV100850997; called by muse, mutect2
- GRAMD1B | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100454779; called by muse, mutect2
- GRIK2 | c.2546del p.N849Tfs*14 | Frame Shift Del (DEL) | VAF 10/54 reads (19%) | catalogued as rs760757380; called by mutect2, varscan2
- GRIK5 | c.2062C>T p.R688C | Missense Mutation (SNP) | VAF 46/157 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53478685; called by muse, mutect2, varscan2
- GRK6 | c.1622G>A p.G541D | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as rs200510977, COSV62682627; called by muse, mutect2, varscan2
- GSE1 | c.366del p.V123Wfs*2 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | catalogued as rs754199513; called by mutect2, varscan2
- GSTCD | c.457A>T p.T153S (on ENST00000360505 / NM_001031720.3; = p.T66S on NM_024751.3) | Missense Mutation (SNP) | VAF 42/426 reads (10%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as COSV100853840; called by muse, mutect2, varscan2
- GSTK1 | c.373G>A p.V125I | Missense Mutation (SNP) | VAF 68/210 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757110852, COSV64424292; called by muse, mutect2, varscan2
- GTF3C3 | c.2104C>T p.L702F | Missense Mutation (SNP) | VAF 65/221 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as COSV55832156; called by muse, mutect2, varscan2
- GTPBP3 | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.771); catalogued as COSV50177675; called by muse, mutect2, varscan2
- H2AC12 | c.95A>G p.H32R | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.453); catalogued as rs1399543247, COSV100804679; called by muse, mutect2, varscan2
- H4C1 | c.89T>G p.I30S | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99772044, COSV99772055; called by muse, mutect2, varscan2
- HAPLN3 | c.964C>T p.R322C | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199517111, COSV100613748; called by muse, mutect2
- HAS1 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV99708417; called by muse, mutect2
- HAUS3 | c.1351C>A p.L451I | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as COSV54722764, COSV54722797; called by muse, mutect2, varscan2
- HAUS5 | c.943C>T p.R315W | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.343); catalogued as rs747319351, COSV52547941; called by muse, mutect2, varscan2
- HDGFL1 | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.897); catalogued as COSV57751109; called by muse, mutect2
- HEATR1 | c.1640A>G p.H547R | Missense Mutation (SNP) | VAF 64/184 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as rs1431845727, COSV63981159; called by muse, mutect2, varscan2
- HEATR9 | c.1226C>T p.A409V | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.577); catalogued as rs746875869; called by muse, mutect2, varscan2
- HECW1 | c.2066G>T p.S689I | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.852); catalogued as COSV67829672; called by muse, mutect2, varscan2
- HES5 | c.276C>A p.Y92* | Nonsense Mutation (SNP) | VAF 9/35 reads (26%) | catalogued as COSV65830262; called by muse, mutect2, varscan2
- HFM1 | c.4295A>G p.D1432G | Missense Mutation (SNP) | VAF 215/704 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.283); catalogued as COSV54027399; called by muse, mutect2, varscan2
- HIC2 | c.47G>A p.R16H | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); catalogued as rs764207081, COSV68042090; called by muse, mutect2, varscan2
- HLA-A | c.627del p.K210Rfs*4 | Frame Shift Del (DEL) | VAF 96/284 reads (34%) | catalogued as rs199474609; called by mutect2, varscan2
- HMBS | c.400C>A p.L134I | Missense Mutation (SNP) | VAF 49/149 reads (33%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.841); catalogued as COSV53828518; called by muse, mutect2, varscan2
- HMG20A | c.480G>T p.K160N | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60312535; called by muse, mutect2, varscan2
- HORMAD1 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 47/220 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV100464179; called by muse, mutect2, varscan2
- HOXA3 | c.904del p.Q302Rfs*74 | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | catalogued as rs761726531; called by mutect2, varscan2
- HRH3 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as rs747290921, COSV58048582; called by muse, mutect2, varscan2
- HSD17B14 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.187); catalogued as rs1417910002, COSV54413502; called by muse, mutect2, varscan2
- HSPA2 | c.598A>G p.I200V | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99904957; called by muse, mutect2, varscan2
- HTR3B | c.1321G>A p.V441M | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as rs140308093; called by muse, mutect2, varscan2
- HUWE1 | c.5587G>T p.G1863C | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99470624; called by muse, mutect2, varscan2
- IDE | c.2594C>T p.A865V | Missense Mutation (SNP) | VAF 106/380 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.097); catalogued as rs1346830197, COSV56423407; called by muse, mutect2, varscan2
- IDH3G | c.650C>T p.T217M | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs782671638, COSV54207621; called by muse, mutect2, varscan2
- IDS | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 45/411 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.172); catalogued as rs1391120386, COSV100558017; called by muse, mutect2, varscan2
- IGSF8 | c.1282C>T p.R428W | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs777061327, COSV58757947; called by muse, mutect2, varscan2
- IGSF9 | c.154dup p.L52Pfs*27 | Frame Shift Ins (INS) | VAF 12/40 reads (30%) | catalogued as rs753928344; called by mutect2, varscan2
- IL17RD | c.1289T>C p.V430A | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV56338081; called by muse, mutect2, varscan2
- IL2RG | c.1082del p.P361Hfs*5 | Frame Shift Del (DEL) | VAF 36/165 reads (22%) | catalogued as rs745545309; called by mutect2, varscan2
- IL4I1 | c.449A>C p.H150P | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as COSV62009986; called by muse, mutect2, varscan2
- IL7 | c.408G>T p.K136N | Missense Mutation (SNP) | VAF 70/193 reads (36%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.89); catalogued as COSV99804985, COSV99805293; called by muse, mutect2, varscan2
- IMPDH2 | c.187A>G p.T63A | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.035); catalogued as COSV58707939; called by muse, mutect2, varscan2
- INF2 | c.2356C>A p.L786M | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53032563; called by muse, mutect2, varscan2
- INPP5D | c.2780T>C p.L927P (on ENST00000445964 / NM_001017915.3; = p.L926P on NM_005541.5) | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.466); catalogued as COSV64040884; called by muse, mutect2, varscan2
- INSM2 | c.865G>A p.V289I | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.52); catalogued as COSV51879730; called by muse, mutect2, varscan2
- IP6K2 | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 26/186 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); catalogued as rs575264529, COSV60793798; called by muse, mutect2, varscan2
- IPO11 | c.1477C>T p.R493* | Nonsense Mutation (SNP) | VAF 27/84 reads (32%) | catalogued as rs1297677377, COSV57576352; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.1411G>A p.V471I (on ENST00000485419 / NM_001197113.1; = p.V395I on NM_014575.3) | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.991); catalogued as rs143827102; called by muse, mutect2, varscan2
- IQGAP1 | c.4457C>T p.A1486V | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.941); catalogued as COSV99185021; called by muse, mutect2, varscan2
- IRF7 | c.433G>A p.E145K (on ENST00000397566; = p.E132K on NM_001572.5) | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0.163); catalogued as COSV99200581; called by muse, mutect2, varscan2
- IRS4 | c.3334C>A p.L1112I | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); catalogued as COSV64533850; called by muse, mutect2, varscan2
- IRX5 | c.1258C>T p.H420Y | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.747); catalogued as COSV58058899; called by muse, mutect2
- IRX6 | c.1274C>T p.A425V | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV51859171; called by mutect2, varscan2
- ISG20L2 | c.865del p.L289Sfs*15 | Frame Shift Del (DEL) | VAF 39/120 reads (33%) | catalogued as rs761558950, COSV57459436; called by mutect2, varscan2
- ITGA8 | c.1445+2T>G p.X482_splice | Splice Site (SNP) | VAF 7/45 reads (16%) | catalogued as COSV100959222; called by muse, mutect2, varscan2
- ITGB3 | c.1628C>T p.T543M | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs770430144, COSV101457614; called by muse, mutect2
- ITIH4 | c.971C>A p.P324Q | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.281); catalogued as COSV56574103; called by muse, mutect2, varscan2
- ITPR3 | c.3599T>C p.M1200T | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs1356231010, COSV100967374; called by mutect2, varscan2
- JAK1 | c.1289del p.P430Rfs*2 | Frame Shift Del (DEL) | VAF 15/50 reads (30%) | catalogued as rs755650243; called by mutect2, pindel, varscan2
- JAK2 | c.1940T>C p.I647T | Missense Mutation (SNP) | VAF 91/252 reads (36%) | SIFT tolerated (0.66); PolyPhen benign (0.207); catalogued as rs758475474, COSV67612440; called by muse, varscan2
- JAKMIP3 | c.1641G>T p.Q547H | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV53823272; called by muse, mutect2
- KANK1 | c.3608C>A p.A1203E | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66528070; called by mutect2, varscan2
- KANSL1L | c.2755G>A p.A919T | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0.009); catalogued as COSV55992358; called by muse, mutect2, varscan2
- KAT14 | c.1906G>A p.A636T | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.173); catalogued as rs746718890, COSV66607717; called by muse, mutect2, varscan2
- KATNAL1 | c.1133_1134dup p.P379Yfs*13 | Frame Shift Ins (INS) | VAF 18/82 reads (22%) | catalogued as rs766322798; called by mutect2, varscan2
- KBTBD3 | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 52/169 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1229989939, COSV73241421; called by muse, mutect2, varscan2
- KCNA2 | c.1160G>A p.G387E | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100315974; called by muse, mutect2, varscan2
- KCNT2 | c.2140T>C p.Y714H | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); catalogued as COSV54080145; called by muse, mutect2, varscan2
- KCTD18 | c.1163C>T p.A388V | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs368312102; called by muse, mutect2, varscan2
- KCTD8 | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 28/283 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as rs769382363, COSV63585801; called by muse, varscan2
- KDM4A | c.2614G>A p.D872N | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.878); catalogued as COSV64959579; called by muse, mutect2, varscan2
- KDM6B | c.1318C>T p.P440S | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV54681628; called by muse, mutect2, varscan2
- KDM6B | c.4868G>A p.R1623H | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.081); catalogued as COSV99641477; called by muse, mutect2
- KIAA0100 | c.4184C>T p.A1395V | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV66492815; called by muse, mutect2, varscan2
- KIAA1614 | c.1834C>A p.L612M | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV62550895; called by muse, mutect2, varscan2
- KIF1B | c.419A>G p.Y140C | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV55808868; called by muse, mutect2, varscan2
- KIF4A | c.190G>A p.V64I | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.761); catalogued as COSV53452727; called by muse, mutect2, varscan2
- KIR2DL1 | c.817del p.N273Mfs*4 | Frame Shift Del (DEL) | VAF 51/105 reads (49%) | catalogued as rs1220669390; called by mutect2, pindel, varscan2
- KLF17 | c.930G>T p.E310D | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.682); catalogued as COSV64856307; called by muse, mutect2, varscan2
- KLF8 | c.310C>A p.L104I | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.775); catalogued as rs1047950271, COSV63847830; called by muse, mutect2, varscan2
- KLHL35 | c.1360G>A p.V454I | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as rs777338493, COSV66219341; called by muse, mutect2, varscan2
- KLHL8 | c.647T>G p.L216R | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56747844; called by muse, mutect2, varscan2
- KLHL9 | c.1762C>T p.R588* | Nonsense Mutation (SNP) | VAF 59/177 reads (33%) | catalogued as COSV62921599; called by muse, mutect2, varscan2
- KMT2D | c.6354del p.A2119Lfs*25 | Frame Shift Del (DEL) | VAF 10/75 reads (13%) | catalogued as COSV56474038; called by mutect2, pindel, varscan2
- KMT2D | c.3937C>T p.R1313W | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769189340, COSV56440234; called by muse, mutect2, varscan2
- KNL1 | c.5014A>G p.R1672G (on ENST00000346991 / NM_170589.5; = p.R1646G on NM_144508.5) | Missense Mutation (SNP) | VAF 13/155 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as COSV61154879; called by muse, mutect2
- KRT76 | c.1471G>A p.G491R | Missense Mutation (SNP) | VAF 87/163 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1176950636, COSV60119809; called by muse, mutect2, varscan2
- LAGE3 | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.049); catalogued as COSV62074219; called by muse, mutect2, varscan2
- LAMA3 | c.3794C>A p.P1265H | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58068771; called by muse, mutect2, varscan2
- LAMA4 | c.3307C>T p.R1103C (on ENST00000230538 / NM_001105206.3; = p.R1096C on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs113109272; called by muse, mutect2, varscan2
- LAMC1 | c.1129G>A p.A377T | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.278); catalogued as rs756781572, COSV51142094; called by mutect2, varscan2
- LARGE1 | c.922C>T p.R308W | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761167014, COSV61658043; called by muse, mutect2, varscan2
- LBH | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101257786; called by muse, mutect2, varscan2
- LCOR | c.2153T>C p.M718T | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV53715922; called by muse, mutect2, varscan2
- LCT | c.5402C>T p.A1801V | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as COSV51549535; called by muse, mutect2, varscan2
- LDB2 | c.234C>T p.Y78= | Splice Region (SNP) | VAF 38/106 reads (36%) | catalogued as rs540696408, COSV100453780; called by muse, mutect2, varscan2
- LENG1 | c.428G>A p.G143D | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.106); catalogued as COSV55363331; called by muse, mutect2, varscan2
- LHX1 | c.1194del p.E399Kfs*2 | Frame Shift Del (DEL) | VAF 19/46 reads (41%) | catalogued as rs775423572; called by mutect2, pindel, varscan2
- LIN52 | c.104T>C p.V35A | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV73465899; called by muse, mutect2, varscan2
- LIPC | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.038); catalogued as rs773316456, COSV100134586; called by mutect2, varscan2
- LMBRD1 | c.866G>A p.R289H (on ENST00000649011; = p.R267H on NM_018368.4) | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.044); catalogued as rs140874824; called by muse, mutect2, varscan2
- LMO7 | c.4984+1G>A p.X1662_splice (on ENST00000357063; = p.X1343_splice on NM_005358.5) | Splice Site (SNP) | VAF 7/31 reads (23%) | catalogued as COSV58550750; called by muse, mutect2, varscan2
- LMOD1 | c.67A>T p.T23S | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.426); catalogued as COSV66172712; called by muse, mutect2, varscan2
- LRBA | c.616T>C p.F206L | Missense Mutation (SNP) | VAF 96/253 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as COSV63952307, COSV63955626; called by muse, varscan2
- LRCH4 | c.1365C>T p.N455= | Splice Region (SNP) | VAF 24/75 reads (32%) | catalogued as rs199833602, COSV59643277; called by muse, mutect2, varscan2
- LRCH4 | c.998G>A p.R333Q | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.035); catalogued as rs191101243; called by muse, mutect2, varscan2
- LRFN4 | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.8); PolyPhen benign (0.121); catalogued as rs1311159229, COSV58921600; called by muse, mutect2, varscan2
- LRIG1 | c.961C>T p.R321W | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs769741661, COSV99833794; called by muse, mutect2, varscan2
- LRIT3 | c.734G>A p.R245Q | Missense Mutation (SNP) | VAF 60/188 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.18); catalogued as rs367757242; called by muse, mutect2, varscan2
- LRRC1 | c.1370C>T p.A457V | Missense Mutation (SNP) | VAF 65/173 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs774261475, COSV63829137; called by muse, mutect2, varscan2
- LRRC18 | c.446T>C p.V149A | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as COSV53282823; called by muse, mutect2
- LRRK2 | c.3619G>A p.D1207N | Missense Mutation (SNP) | VAF 46/220 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV54153485; called by muse, mutect2, varscan2
- LRRTM3 | c.1493C>T p.T498M | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); catalogued as COSV63665589; called by muse, mutect2, varscan2
- LSAMP | c.44T>C p.V15A | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV61291227; called by muse, mutect2, varscan2
- LSP1 | c.322dup p.Q108Pfs*6 | Frame Shift Ins (INS) | VAF 15/68 reads (22%) | catalogued as rs752018434; called by mutect2, varscan2
- LTF | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 90/277 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.79); catalogued as rs776865450, COSV51606041; called by muse, varscan2
- LUZP1 | c.1295C>T p.A432V | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.124); catalogued as COSV56501182; called by muse, mutect2, varscan2
- LY6G5B | c.8T>A p.V3D | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.086); catalogued as rs1302801471, COSV65507875; called by mutect2, varscan2
- MAB21L2 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100462168; called by muse, mutect2, varscan2
- MACC1 | c.1309A>G p.I437V | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs923576419, COSV100255828, COSV100256012; called by muse, varscan2
- MACC1 | c.1232del p.N411Tfs*23 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | catalogued as rs761473889, COSV60540689; called by pindel, varscan2
- MAGEB1 | c.352T>G p.F118V | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV66775741; called by muse, mutect2, varscan2
- MAGEC3 | c.1097C>T p.A366V | Missense Mutation (SNP) | VAF 52/111 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as rs760095164, COSV53580394; called by muse, mutect2, varscan2
- MAL | c.359G>T p.R120M | Missense Mutation (SNP) | VAF 44/202 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as COSV59431448; called by muse, mutect2, varscan2
- MAN1A2 | c.1654C>T p.Q552* | Nonsense Mutation (SNP) | VAF 44/137 reads (32%) | catalogued as COSV62978515; called by muse, mutect2, varscan2
- MAN2A1 | c.2473C>T p.P825S | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as rs776345595, COSV99811107; called by mutect2, varscan2
- MAP1B | c.754G>T p.G252C | Missense Mutation (SNP) | VAF 56/159 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99702406; called by muse, mutect2, varscan2
- MAP2K7 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs758493704, COSV67608277; called by muse, mutect2, varscan2
- MAP3K9 | c.470A>T p.K157M | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV67121358; called by muse, mutect2, varscan2
- MAP4K5 | c.793dup p.R265Kfs*5 | Frame Shift Ins (INS) | VAF 40/160 reads (25%) | catalogued as rs746424357; called by mutect2, varscan2
- MAP7 | c.1367C>T p.A456V | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV63419759; called by muse, mutect2, varscan2
- MAP7D1 | c.245dup p.Q83Afs*8 | Frame Shift Ins (INS) | VAF 12/51 reads (24%) | catalogued as rs765962881; called by mutect2, varscan2
- MBD4 | c.150G>T p.E50D | Missense Mutation (SNP) | VAF 71/219 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.591); catalogued as COSV51444649; called by muse, mutect2, varscan2
- MBD6 | c.1997del p.P666Hfs*9 | Frame Shift Del (DEL) | VAF 19/89 reads (21%) | catalogued as COSV63073363; called by mutect2, pindel, varscan2
- MCOLN1 | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 106/342 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.022); catalogued as rs377681899; called by muse, mutect2, varscan2
- MDGA1 | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs368622840; called by muse, mutect2, varscan2
- MDGA2 | c.2651T>A p.L884H (on ENST00000399232 / NM_001113498.2; = p.L586H on NM_182830.4) | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62093235, COSV62118191; called by muse, mutect2, varscan2
- MDN1 | c.5966del p.K1989Rfs*65 | Frame Shift Del (DEL) | VAF 25/54 reads (46%) | catalogued as rs750092100; called by mutect2, varscan2
- MED12L | c.454C>T p.P152S | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV56369033; called by muse, mutect2, varscan2
- MEF2D | c.1310G>A p.S437N | Missense Mutation (SNP) | VAF 56/204 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as rs952787007, COSV61728308; called by muse, mutect2, varscan2
- MEGF10 | c.528G>A p.W176* | Nonsense Mutation (SNP) | VAF 26/65 reads (40%) | catalogued as COSV57249246; called by muse, mutect2, varscan2
- MET | c.2684C>T p.T895M | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.749); catalogued as rs199502137; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- METTL15 | c.651G>T p.Q217H | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV57719958; called by muse, mutect2, varscan2
- METTL24 | c.708T>G p.H236Q | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.588); catalogued as COSV58822153; called by muse, mutect2, varscan2
- MEX3A | c.1542A>C p.Q514H | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV68479097; called by muse, varscan2
- MEX3A | c.1493G>A p.C498Y | Missense Mutation (SNP) | VAF 58/181 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV68479100; called by muse, varscan2
- MFSD2B | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs1224346311, COSV57854719; called by muse, mutect2, varscan2
- MGAT5B | c.191del p.G64Afs*11 | Frame Shift Del (DEL) | VAF 5/39 reads (13%) | catalogued as rs963709095, COSV100047240; called by mutect2, pindel, varscan2
- MIB1 | c.2701C>T p.R901* | Nonsense Mutation (SNP) | VAF 73/299 reads (24%) | catalogued as rs369135845; called by muse, mutect2, varscan2
- MIB2 | c.2518del p.D840Tfs*22 | Frame Shift Del (DEL) | VAF 15/81 reads (19%) | catalogued as rs747046371; called by mutect2, varscan2
- MINDY2 | c.148G>A p.G50S | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as rs1352253384, COSV57506750; called by muse, mutect2, varscan2
- MIP | c.572C>A p.P191H | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57511411; called by muse, mutect2, varscan2
- MIS18BP1 | c.1139del p.N380Ifs*3 | Frame Shift Del (DEL) | VAF 30/98 reads (31%) | catalogued as rs751180035; called by mutect2, varscan2
- MLLT6 | c.2795T>C p.L932P | Missense Mutation (SNP) | VAF 40/292 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1460435894; called by muse, varscan2
- MLXIPL | c.1916G>A p.R639Q | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.921); catalogued as rs781908299, COSV57668202; called by muse, mutect2, varscan2
- MMEL1 | c.799G>T p.G267C | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.801); catalogued as COSV56521548; called by muse, mutect2
- MORN5 | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs138145529; called by muse, mutect2, varscan2
- MPDZ | c.1dup p.M1? | Frame Shift Ins (INS) | VAF 14/43 reads (33%) | catalogued as rs769613339; called by mutect2, varscan2
- MRAP2 | c.512A>T p.N171I | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV57632488; called by muse, mutect2, varscan2
- MROH1 | c.837G>T p.E279D | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as COSV58189488; called by muse, mutect2, varscan2
- MROH5 | c.2044G>T p.E682* | Nonsense Mutation (SNP) | VAF 10/102 reads (10%) | catalogued as COSV101436002; called by muse, mutect2
- MRTFA | c.1861C>T p.R621C | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.866); catalogued as rs373666097, COSV62933025, COSV62935045; called by muse, mutect2, varscan2
- MS4A7 | c.13T>C p.S5P | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100279551; called by muse, mutect2
- MST1R | c.2495G>A p.R832Q | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.045); catalogued as rs769911110, COSV56568838; called by muse, mutect2, varscan2
- MSX1 | c.809C>T p.S270L | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.445); catalogued as COSV66947295; called by muse, mutect2, varscan2
- MTG1 | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs148997160; called by muse, mutect2, varscan2
- MTMR7 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.419); catalogued as rs1325657111, COSV99472445; called by muse, varscan2
- MTMR9 | c.584del p.N195Mfs*4 | Frame Shift Del (DEL) | VAF 10/62 reads (16%) | catalogued as rs767880823; called by mutect2, varscan2
- MTURN | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.06); catalogued as rs138966019; called by muse, mutect2, varscan2
- MUC16 | c.42575C>T p.A14192V | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.961); catalogued as COSV66690500, COSV66692037; called by muse, mutect2, varscan2
- MUC16 | c.37615G>T p.A12539S | Missense Mutation (SNP) | VAF 55/186 reads (30%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.053); catalogued as COSV67466399; called by muse, mutect2, varscan2
- MUC5B | c.5342C>T p.T1781M | Missense Mutation (SNP) | VAF 50/153 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs370364390; called by muse, mutect2, varscan2
- MXRA5 | c.6440G>A p.R2147H | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV54229047, COSV54244657; called by muse, mutect2, varscan2
- MYCBP2 | c.3548C>T p.A1183V (on ENST00000357337; = p.A1221V on NM_015057.5) | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.135); catalogued as COSV62019515; called by muse, mutect2, varscan2
- MYH8 | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 79/248 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs940074051, COSV67965237; called by muse, mutect2, varscan2
- MYL9 | c.20A>G p.K7R | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.229); catalogued as COSV54072428; called by muse, mutect2, varscan2
- MYMK | c.643A>G p.T215A | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.138); catalogued as COSV101301151; called by muse, mutect2, varscan2
- MYNN | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs764466451, COSV62991324; called by mutect2, varscan2
- MYO10 | c.5191C>T p.R1731* | Nonsense Mutation (SNP) | VAF 16/70 reads (23%) | catalogued as rs771074228, COSV57021762, COSV99945895; called by muse, mutect2, varscan2
- MYPN | c.616C>T p.R206* | Nonsense Mutation (SNP) | VAF 13/42 reads (31%) | catalogued as COSV62731979; called by muse, mutect2, varscan2
- MYRF | c.499T>C p.C167R (on ENST00000278836 / NM_001127392.3; = p.C158R on NM_013279.4) | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99607125; called by muse, mutect2
- MYRF | c.1085C>T p.A362V (on ENST00000278836 / NM_001127392.3; = p.A353V on NM_013279.4) | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.017); catalogued as rs757350022, COSV53887778; called by muse, varscan2
- NAA16 | c.1108C>T p.P370S | Missense Mutation (SNP) | VAF 72/236 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV101038344, COSV101038414; called by muse, mutect2, varscan2
- NAAA | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1223566479, COSV99715929; called by muse, mutect2
- NAALADL1 | c.2060del p.T687Rfs*4 | Frame Shift Del (DEL) | VAF 14/67 reads (21%) | catalogued as COSV57246981; called by mutect2, pindel, varscan2
- NAALADL2 | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs1359862591, COSV101435765; called by muse, mutect2, varscan2
- NAALADL2 | c.1036A>G p.M346V | Missense Mutation (SNP) | VAF 32/233 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101380158; called by muse, mutect2, varscan2
- NAB1 | c.274A>G p.S92G | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.615); catalogued as rs376386678, COSV61609494; called by mutect2, varscan2
- NAE1 | c.1451G>A p.R484Q | Missense Mutation (SNP) | VAF 65/174 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762421870, COSV99323136; called by muse, mutect2, varscan2
- NALCN | c.2122C>T p.R708C | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.386); catalogued as rs780641051, COSV51936196; called by muse, mutect2, varscan2
- NALCN | c.1207A>G p.S403G | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.374); catalogued as COSV51936202; called by muse, mutect2, varscan2
- NAP1L2 | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 29/175 reads (17%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.047); catalogued as COSV65172511; called by muse, mutect2, varscan2
- NAP1L3 | c.269C>G p.A90G | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs756672363, COSV59077137; called by muse, mutect2, varscan2
- NAPEPLD | c.802G>T p.G268C | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.122); catalogued as COSV100439857; called by muse, mutect2, varscan2
- NAV1 | c.481del p.L161Wfs*33 | Frame Shift Del (DEL) | VAF 11/35 reads (31%) | catalogued as rs1346393455; called by mutect2, pindel, varscan2
- NBEAL2 | c.5555T>C p.L1852P | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.222); catalogued as rs867630841, COSV99435992; called by muse, mutect2, varscan2
- NCKAP5 | c.4084C>T p.H1362Y | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); catalogued as COSV58444326; called by muse, mutect2, varscan2
- NCOA5 | c.8C>T p.T3M | Missense Mutation (SNP) | VAF 28/216 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.738); catalogued as rs755272201, COSV51644439; called by muse, mutect2, varscan2
- NCOR2 | c.3482T>C p.L1161P | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); catalogued as COSV62305656; called by muse, mutect2, varscan2
- NDN | c.845T>C p.V282A | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV100086453; called by muse, mutect2, varscan2
- NDST3 | c.1216T>A p.F406I | Missense Mutation (SNP) | VAF 41/165 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV56619113; called by muse, varscan2
- NECTIN4 | c.418C>T p.R140W | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV63512642; called by muse, mutect2, varscan2
- NEIL3 | c.1031G>A p.R344K | Missense Mutation (SNP) | VAF 49/154 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.106); catalogued as rs1483293215, COSV52810491, COSV52811457; called by muse, mutect2, varscan2
- NEK10 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1049804439, COSV58283534; called by muse, mutect2, varscan2
- NEMF | c.3146G>A p.S1049N | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1241461482, COSV53587304; called by muse, mutect2, varscan2
- NES | c.1464A>T p.R488S | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.027); catalogued as COSV63961091; called by muse, mutect2, varscan2
- NES | c.1285C>T p.R429W | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751310959, COSV63961095; called by muse, mutect2, varscan2
- NEUROD1 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 65/506 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV54548947, COSV99717089; called by muse, mutect2, varscan2
- NEUROG1 | c.362C>T p.S121L | Missense Mutation (SNP) | VAF 108/336 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV100130797; called by muse, varscan2
- NEXMIF | c.2528G>T p.G843V | Missense Mutation (SNP) | VAF 55/161 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV50031341; called by muse, mutect2, varscan2
- NEXN | c.914A>G p.Y305C | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.619); catalogued as rs541547470, COSV53942963; called by muse, mutect2, varscan2
- NFE2L1 | c.1696C>T p.P566S | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV62583222; called by muse, mutect2, varscan2
- NFX1 | c.2086C>T p.R696W | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs186044438; called by muse, mutect2, varscan2
- NKX2-5 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61299075; called by muse, mutect2, varscan2
- NLE1 | c.1154G>A p.R385H | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs200560049, COSV50101358; called by muse, mutect2, varscan2
- NLE1 | c.986C>T p.A329V | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as COSV62604221, COSV62604583; called by muse, varscan2
- NOD2 | c.2656G>A p.A886T | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.175); catalogued as rs376366287, COSV56050799; called by muse, mutect2, varscan2
- NOL4L | c.396del p.Y133Tfs*20 | Frame Shift Del (DEL) | VAF 18/70 reads (26%) | catalogued as rs751187638; called by mutect2, varscan2
- NOL6 | c.2503C>T p.P835S | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53041824; called by muse, mutect2, varscan2
- NOMO1 | c.2524C>T p.P842S | Missense Mutation (SNP) | VAF 265/909 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99814551; called by muse, mutect2, varscan2
- NOSIP | c.887G>A p.R296Q | Missense Mutation (SNP) | VAF 34/250 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV100182272; called by muse, varscan2
- NOTCH2 | c.362G>A p.C121Y | Missense Mutation (SNP) | VAF 60/383 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV56691612; called by muse, mutect2, varscan2
- NOTCH3 | c.6619C>T p.R2207W | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.539); catalogued as rs753170185, COSV99657321; called by muse, mutect2, varscan2
- NOTCH3 | c.2149C>T p.R717C | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.893); catalogued as rs144163298, CM1414856; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NPAS4 | c.1631G>A p.S544N | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.549); catalogued as COSV60650499; called by muse, mutect2, varscan2
- NPM1 | c.586A>G p.I196V | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as rs376742289; called by muse, mutect2, varscan2
- NPR2 | c.1142T>C p.V381A | Missense Mutation (SNP) | VAF 48/186 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.079); catalogued as COSV100709480; called by muse, mutect2, varscan2
- NQO2 | c.76_77insT p.A26Vfs*4 | Frame Shift Ins (INS) | VAF 30/104 reads (29%) | catalogued as COSV57642839; called by mutect2, pindel*, varscan2
- NR1H3 | c.601del p.Q201Kfs*13 | Frame Shift Del (DEL) | VAF 16/56 reads (29%) | catalogued as rs779801455; called by mutect2, pindel, varscan2
- NR1H3 | c.1309C>T p.P437S | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60624223; called by muse, mutect2, varscan2
- NRBP1 | c.1331T>C p.V444A | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV51996352, COSV99275033; called by muse, mutect2, varscan2
- NSD1 | c.6662A>G p.Y2221C | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1433952610, COSV61773182; called by muse, mutect2, varscan2
- NSMAF | c.1186G>A p.G396S | Missense Mutation (SNP) | VAF 48/133 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); catalogued as COSV50687186; called by muse, mutect2, varscan2
- NTRK1 | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 38/183 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs578095133, COSV62325640; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NUDT12 | c.1023G>T p.R341S | Missense Mutation (SNP) | VAF 40/158 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV50091046; called by muse, mutect2, varscan2
- NUP205 | c.4932G>T p.Q1644H | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99607030; called by muse, mutect2
- NUP210 | c.2347C>T p.R783C | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs201758204; called by muse, mutect2, varscan2
- NUP210L | c.1940C>T p.T647I | Missense Mutation (SNP) | VAF 49/164 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); catalogued as COSV55147761; called by muse, mutect2, varscan2
- NUP50 | c.1343G>A p.R448Q | Missense Mutation (SNP) | VAF 76/250 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201334547, COSV100754221, COSV100754341; called by muse, mutect2, varscan2
- NUTM1 | c.3386G>A p.R1129H | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated (0.3); PolyPhen benign (0.194); catalogued as rs200540515; called by muse, mutect2, varscan2
- OGDHL | c.1043T>C p.V348A | Missense Mutation (SNP) | VAF 74/235 reads (31%) | SIFT tolerated (0.87); PolyPhen benign (0.007); catalogued as COSV100934330, COSV65105032; called by muse, mutect2, varscan2
- OLAH | c.489del p.K164Sfs*10 (on ENST00000378228 / NM_001039702.3; = p.K217Sfs*10 on NM_018324.3) | Frame Shift Del (DEL) | VAF 29/191 reads (15%) | catalogued as rs774581354; called by mutect2, pindel, varscan2
- OLIG2 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.586); catalogued as rs1384417684, COSV60972398; called by muse, mutect2, varscan2
- OR10G7 | c.361C>A p.R121S | Missense Mutation (SNP) | VAF 185/628 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV100389941, COSV57866127; called by muse, mutect2, varscan2
- OR10G9 | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 53/223 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as rs759163319, COSV66686451; called by muse, mutect2, varscan2
- OR10Q1 | c.358G>A p.A120T | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.098); catalogued as COSV57470447; called by muse, mutect2, varscan2
- OR2L8 | c.885G>T p.E295D | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.102); catalogued as COSV61726834; called by muse, mutect2
- OR3A1 | c.235G>A p.V79I | Missense Mutation (SNP) | VAF 23/194 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs376929342; called by muse, mutect2, varscan2
- OR4A47 | c.34C>T p.L12F | Missense Mutation (SNP) | VAF 78/253 reads (31%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.172); catalogued as rs771715944, COSV71444957; called by muse, mutect2, varscan2
- OR4N2 | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 45/264 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.072); catalogued as rs756329406, COSV60050348; called by mutect2, varscan2
- OR52N5 | c.893A>T p.N298I | Missense Mutation (SNP) | VAF 76/262 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100399700; called by muse, mutect2, varscan2
- OR5D13 | c.53G>A p.G18D | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as rs1429783415, COSV62333738; called by muse, mutect2, varscan2
- OR5D18 | c.336A>C p.E112D | Missense Mutation (SNP) | VAF 64/339 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.32); catalogued as COSV61737128; called by muse, mutect2, varscan2
- OR6K2 | c.727G>C p.V243L | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as rs1190076234, COSV62743486; called by muse, mutect2, varscan2
- OR8A1 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 25/175 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV52508667; called by muse, mutect2, varscan2
- OR8D2 | c.751T>C p.F251L | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs1220480589, COSV100659000, COSV100659148; called by muse, mutect2, varscan2
- OR8H2 | c.322G>T p.G108C | Missense Mutation (SNP) | VAF 112/390 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.687); catalogued as COSV100542335; called by muse, mutect2, varscan2
- OR8J1 | c.257del p.L86* | Frame Shift Del (DEL) | VAF 83/284 reads (29%) | catalogued as rs781156862, COSV57320084; called by mutect2, pindel, varscan2
- ORM2 | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 104/463 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.854); catalogued as rs748201206, COSV99407551; called by muse, mutect2, varscan2
- OSBPL11 | c.1345T>G p.Y449D | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56174045; called by muse, mutect2, varscan2
- OSGIN2 | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 112/322 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs533674331, COSV52408402; called by muse, mutect2, varscan2
- OSMR | c.2513T>C p.L838P | Missense Mutation (SNP) | VAF 66/139 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.927); catalogued as COSV57085165; called by muse, mutect2, varscan2
- OTUB1 | c.428T>C p.M143T | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55360652; called by muse, mutect2, varscan2
- OTX2 | c.857T>A p.F286Y (on ENST00000408990 / NM_172337.3; = p.F294Y on NM_021728.4) | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.571); catalogued as COSV59766113; called by mutect2, varscan2
- P2RX1 | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs558236308, COSV99844754; called by muse, varscan2
- P2RX4 | c.320T>C p.L107P | Missense Mutation (SNP) | VAF 51/100 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.723); catalogued as COSV58742366; called by muse, mutect2, varscan2
- PABPC4 | c.224A>G p.D75G | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV65723397; called by muse, mutect2, varscan2
- PACSIN1 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.618); catalogued as COSV55058417; called by muse, mutect2, varscan2
- PAK5 | c.854G>T p.R285M | Missense Mutation (SNP) | VAF 42/273 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV62027651; called by muse, mutect2, varscan2
- PAN2 | c.1493A>G p.Y498C | Missense Mutation (SNP) | VAF 37/325 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57753888; called by muse, mutect2, varscan2
- PAPPA2 | c.5055del p.S1686Vfs*4 | Frame Shift Del (DEL) | VAF 40/126 reads (32%) | catalogued as rs747970462, COSV62809272; called by mutect2, varscan2
- PARD3B | c.829G>A p.A277T | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1332646238, COSV62507528; called by muse, mutect2, varscan2
- PARP6 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated, low confidence (0.23); PolyPhen probably damaging (0.984); catalogued as rs764588650, COSV53003229; called by muse, mutect2, varscan2
- PAX2 | c.235A>G p.K79E | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62291169; called by muse, mutect2, varscan2
- PCDH10 | c.360dup p.S121Lfs*13 | Frame Shift Ins (INS) | VAF 10/34 reads (29%) | catalogued as rs759095467; called by mutect2, varscan2
- PCDHA2 | c.2381T>C p.V794A | Missense Mutation (SNP) | VAF 64/472 reads (14%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.005); catalogued as rs1554120415, COSV65370592; called by muse, mutect2, varscan2
- PCDHA6 | c.1108G>A p.A370T | Missense Mutation (SNP) | VAF 101/352 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.823); catalogued as COSV65352427; called by muse, mutect2, varscan2
- PCDHB10 | c.1307A>G p.N436S | Missense Mutation (SNP) | VAF 52/172 reads (30%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.012); catalogued as rs1388957083, COSV99504358; called by muse, varscan2
- PCDHB15 | c.1223C>T p.A408V | Missense Mutation (SNP) | VAF 9/134 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.148); catalogued as rs782490140, COSV50973234; called by muse, mutect2
- PCDHB2 | c.1972G>A p.A658T | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.056); catalogued as COSV50565755; called by muse, varscan2
- PCDHB8 | c.282G>T p.E94D | Missense Mutation (SNP) | VAF 68/711 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99176972; called by muse, mutect2, varscan2
- PCDHB9 | c.1505C>G p.S502C | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.89); catalogued as COSV53381274; called by muse, mutect2, varscan2
- PCDHGA10 | c.2002G>A p.V668M | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.634); catalogued as rs758980730, COSV53949230; called by muse, mutect2, varscan2
- PCDHGA5 | c.1648C>A p.L550M | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as COSV53949128, COSV99545969; called by muse, mutect2, varscan2
- PCDHGB7 | c.826G>T p.E276* | Nonsense Mutation (SNP) | VAF 26/58 reads (45%) | catalogued as COSV53949243; called by muse, mutect2, varscan2
- PCGF1 | c.485A>G p.Y162C | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.706); catalogued as rs78921032, COSV52043163; called by muse, mutect2, varscan2
- PCNT | c.1639G>T p.G547W | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV64028273; called by muse, mutect2, varscan2
- PDE4A | c.637G>A p.G213S | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0.011); catalogued as rs1288389575, COSV53355967, COSV99534712; called by muse, mutect2, varscan2
- PDE4A | c.719G>T p.W240L | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.26); catalogued as COSV53356007; called by muse, mutect2, varscan2
- PDLIM1 | c.509G>A p.S170N | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV61474015; called by muse, mutect2, varscan2
- PEX5 | c.1642G>A p.A548T (on ENST00000420616; = p.A540T on NM_000319.5) | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99870939; called by muse, mutect2, varscan2
- PFKP | c.1609G>A p.A537T | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as rs762200045, COSV66897719, COSV66901885; called by muse, mutect2, varscan2
- PGAM1 | c.535A>G p.K179E | Missense Mutation (SNP) | VAF 30/179 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.087); catalogued as COSV58356396; called by muse, mutect2, varscan2
- PHF2 | c.1475del p.K492Rfs*6 | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | catalogued as rs769717544; called by mutect2, varscan2
- PHF21B | c.805C>T p.R269W | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs755504448, COSV57558385; called by muse, mutect2, varscan2
- PHIP | c.3379+2T>C p.X1127_splice | Splice Site (SNP) | VAF 30/220 reads (14%) | catalogued as COSV99244164; called by muse, mutect2, varscan2
- PHOSPHO1 | c.586G>T p.E196* | Nonsense Mutation (SNP) | VAF 11/42 reads (26%) | catalogued as rs865861744, COSV56800122; called by muse, mutect2, varscan2
- PIAS2 | c.727-1G>T p.X243_splice | Splice Site (SNP) | VAF 10/88 reads (11%) | catalogued as COSV61343312; called by muse, mutect2, varscan2
- PIGW | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 57/186 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs997305566; called by muse, mutect2, varscan2
- PIK3CA | c.670G>T p.A224S | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as COSV55928193; called by muse, mutect2, varscan2
- PITPNA | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs369131097; called by muse, mutect2, varscan2
- PITPNM1 | c.3688C>T p.R1230W | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.541); catalogued as rs369506944, COSV54161597; called by muse, mutect2, varscan2
- PKD2L1 | c.1967A>C p.K656T | Missense Mutation (SNP) | VAF 38/179 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as COSV100559382; called by muse, mutect2, varscan2
- PKN1 | c.2756G>A p.R919H | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as rs1452527175, COSV52875152; called by muse, varscan2
- PKP1 | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs151214763; called by muse, mutect2, varscan2
- PKP2 | c.815G>T p.R272M | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV50730976; called by muse, mutect2, varscan2
- PKP3 | c.961C>A p.L321M | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT tolerated (0.76); PolyPhen benign (0.014); catalogued as COSV58987181; called by muse, mutect2, varscan2
- PLA2G3 | c.1382G>A p.R461Q | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs150202365, COSV53213006; called by muse, mutect2, varscan2
- PLCB3 | c.2083C>T p.R695C | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.37); catalogued as rs776651979, COSV54188555; called by muse, mutect2, varscan2
- PLCD1 | c.1580G>A p.R527H | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs781358862, COSV52184686; called by muse, mutect2, varscan2
- PLCXD2 | c.137T>C p.L46P | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.211); catalogued as COSV101210072; called by muse, mutect2, varscan2
- PLEC | c.8429C>T p.A2810V (on ENST00000322810 / NM_201380.4; = p.A2700V on NM_000445.5) | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs368335274; called by muse, mutect2, varscan2
- PLEKHG3 | c.2309G>A p.G770E (on ENST00000394691; = p.G826E on NM_001308147.2) | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.02); catalogued as COSV55980120; called by muse, mutect2, varscan2
- PLK2 | c.1856G>T p.G619V | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57106480, COSV57107352; called by muse, varscan2
- PLSCR3 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.87); catalogued as COSV61170791; called by muse, mutect2, varscan2
- PLXNA1 | c.2053G>A p.V685M | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.105); catalogued as rs767000075, COSV52523154; called by muse, mutect2, varscan2
- PLXNA3 | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1557204207, COSV63754100; called by muse, mutect2, varscan2
- PLXNB3 | c.227A>C p.Q76P | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62797410; called by muse, mutect2, varscan2
- PLXNB3 | c.5681G>A p.R1894H | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs973767706, COSV62797423; called by muse, mutect2, varscan2
- PLXND1 | c.3078-3del | Splice Region (DEL) | VAF 11/46 reads (24%) | catalogued as rs1278682279; called by mutect2, pindel, varscan2
- PM20D1 | c.965G>T p.R322M | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.658); catalogued as COSV65648947; called by muse, mutect2, varscan2
- PMEPA1 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.009); catalogued as COSV55693629; called by muse, mutect2, varscan2
- POLK | c.1226G>T p.R409M | Missense Mutation (SNP) | VAF 122/381 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV54035237; called by muse, mutect2, varscan2
- POLR3E | c.1114G>A p.A372T | Missense Mutation (SNP) | VAF 47/167 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV100242152; called by muse, mutect2, varscan2
- POMK | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.009); catalogued as rs369762572; called by muse, mutect2, varscan2
- POMT2 | c.844C>T p.R282C | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200204831; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POP1 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs767448528, COSV62892779; called by muse, mutect2, varscan2
- POU1F1 | c.257T>C p.L86S | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV60155952; called by muse, mutect2, varscan2
- POU2F1 | c.410T>C p.V137A (on ENST00000541643 / NM_001365848.1; = p.V160A on NM_002697.4) | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.857); catalogued as COSV99611172; called by muse, mutect2, varscan2
- POU4F3 | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV100047063; called by muse, mutect2, varscan2
- PPL | c.4949G>A p.R1650Q | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs147332048; called by muse, mutect2, varscan2
- PPP1R18 | c.496C>A p.P166T | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); catalogued as COSV51299614; called by muse, mutect2, varscan2
- PPP2R3B | c.1291G>A p.A431T | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as COSV66813324; called by muse, mutect2, varscan2
- PPP4R1 | c.1342_1343del p.L448Rfs*6 (on ENST00000400556 / NM_001042388.3; = p.L431Rfs*6 on NM_005134.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 51/204 reads (25%) | catalogued as COSV53281810; called by mutect2, pindel, varscan2
- PPP6R2 | c.1079G>A p.S360N | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.065); catalogued as COSV53293441; called by muse, mutect2, varscan2
- PRAMEF12 | c.1174G>A p.A392T | Missense Mutation (SNP) | VAF 60/208 reads (29%) | SIFT tolerated (0.64); PolyPhen benign (0.026); catalogued as rs781673763, COSV63215323; called by muse, mutect2, varscan2
- PREX2 | c.931G>C p.D311H | Missense Mutation (SNP) | VAF 21/250 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV99906369, COSV99907406; called by muse, mutect2
- PRG4 | c.3090del p.K1030Nfs*14 | Frame Shift Del (DEL) | VAF 20/142 reads (14%) | catalogued as rs746925439; called by mutect2, pindel, varscan2
- PRICKLE3 | c.1303C>T p.R435C | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.661); catalogued as rs897966331, COSV66234588; called by muse, mutect2, varscan2
- PROM2 | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs535604152, COSV58296537; called by muse, mutect2, varscan2
- PRORP | c.257del p.L86* | Frame Shift Del (DEL) | VAF 16/39 reads (41%) | catalogued as rs760446387; called by mutect2, varscan2
- PROZ | c.325T>C p.Y109H | Missense Mutation (SNP) | VAF 44/143 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61439401; called by muse, mutect2, varscan2
- PRSS35 | c.320C>A p.P107Q | Missense Mutation (SNP) | VAF 50/162 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.03); catalogued as COSV100864093, COSV63800426; called by muse, mutect2, varscan2
- PRX | c.4300C>T p.R1434W | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs767488196, COSV99396695; called by muse, mutect2, varscan2
- PSG7 | c.256G>A p.G86S | Missense Mutation (SNP) | VAF 43/166 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as rs781911242, COSV101343203, COSV68444770; called by muse, mutect2, varscan2
- PSPC1 | c.980G>A p.R327H | Missense Mutation (SNP) | VAF 70/218 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.479); catalogued as rs1275173395, COSV58888189; called by muse, mutect2, varscan2
- PTBP1 | c.817C>A p.R273S | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as COSV62459985; called by muse, mutect2, varscan2
- PTGES2 | c.955G>T p.G319C | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99476363; called by muse, mutect2, varscan2
- PTK2B | c.2590G>A p.A864T | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as rs753976890, COSV57756767; called by muse, mutect2, varscan2
- PTPN14 | c.1594G>A p.A532T | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs373438300; called by muse, mutect2, varscan2
- PTPN3 | c.2146G>A p.A716T | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs763936455, COSV52705938; called by mutect2, varscan2
- PTPRS | c.1034C>T p.A345V | Missense Mutation (SNP) | VAF 54/189 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53619936; called by muse, mutect2, varscan2
- PTRH1 | c.80del p.P27Rfs*69 | Frame Shift Del (DEL) | VAF 11/80 reads (14%) | catalogued as rs758395587; called by mutect2, pindel, varscan2
- PYDC1 | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as COSV100265423; called by muse, mutect2, varscan2
- RAB11FIP2 | c.58C>T p.L20F | Missense Mutation (SNP) | VAF 132/470 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV62925233; called by muse, varscan2
- RAB7A | c.213G>C p.Q71H | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as COSV54041672; called by muse, mutect2, varscan2
- RAD54L2 | c.1577G>A p.R526H | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1166870408, COSV56580646; called by muse, mutect2, varscan2
- RAI1 | c.3920G>A p.R1307Q | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs369260099; called by muse, mutect2, varscan2
- RALGAPA2 | c.1447C>T p.R483C | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs747438948, COSV52497832; called by muse, mutect2, varscan2
- RAPGEF4 | c.1385C>T p.A462V | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs1232697175, COSV51389507; called by muse, mutect2, varscan2
- RARG | c.1017A>T p.G339= | Splice Region (SNP) | VAF 41/91 reads (45%) | catalogued as rs1474311064, COSV100553246, COSV58432917; called by muse, mutect2, varscan2
- RARG | c.1016G>T p.G339V | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV58432940, COSV58433799; called by muse, mutect2, varscan2
- RBM10 | c.1495G>A p.A499T | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.942); catalogued as rs781843473, COSV61307822; called by muse, mutect2, varscan2
- RBM42 | c.1396G>A p.V466M | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as rs370094400; called by muse, mutect2, varscan2
- RECQL5 | c.986G>T p.R329M | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58640502; called by muse, mutect2, varscan2
- REPS2 | c.376C>T p.R126W | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs772735900, COSV58182274; called by muse, mutect2, varscan2
- RERE | c.1846G>A p.A616T | Missense Mutation (SNP) | VAF 48/222 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.654); catalogued as rs759860051, COSV61942349; called by muse, mutect2, varscan2
- REV3L | c.1310G>A p.C437Y | Missense Mutation (SNP) | VAF 103/287 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.039); catalogued as COSV62619030; called by muse, mutect2, varscan2
- RGS21 | c.350G>A p.C117Y | Missense Mutation (SNP) | VAF 26/240 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV69882508; called by muse, mutect2
- RGS22 | c.2936G>A p.R979H | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1008009423, COSV62659476; called by muse, mutect2, varscan2
- RIMS2 | c.793G>A p.A265T (on ENST00000666250 / NM_001348490.2; = p.A73T on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.031); catalogued as rs750171549, COSV51664277; called by muse, mutect2, varscan2
- RINL | c.1663T>C p.W555R (on ENST00000591812 / NM_001195833.2; = p.W441R on NM_198445.4) | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs756901954, COSV61574703; called by muse, mutect2, varscan2
- RNASE10 | c.362A>T p.D121V | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV60517719; called by muse, mutect2, varscan2
- RND2 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 68/187 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs144102422, COSV99870023; called by muse, mutect2, varscan2
- RNF145 | c.89A>G p.D30G (on ENST00000424310 / NM_001199383.2; = p.D58G on NM_144726.2) | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as COSV50866466; called by muse, mutect2, varscan2
- RNF41 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0.047); catalogued as rs868335616, COSV61504437; called by muse, mutect2, varscan2
- ROBO2 | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59907550; called by muse, mutect2, varscan2
- ROBO2 | c.3902C>T p.A1301V | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV59943211; called by muse, mutect2, varscan2
- ROR2 | c.2539G>A p.A847T | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.018); catalogued as COSV65219171; called by muse, mutect2, varscan2
- RP1 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 59/171 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs758260528, COSV55110239; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 9/23 reads (39%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPL3L | c.92C>T p.T31M | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as rs548699428, COSV51906695; called by muse, mutect2, varscan2
- RPS5 | c.394G>A p.G132R | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.414); catalogued as COSV52190950; called by muse, mutect2, varscan2
- RPS6KL1 | c.1561C>T p.R521W | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.87); catalogued as rs200816369, COSV53166256; called by muse, mutect2, varscan2
- RPS6KL1 | c.848C>T p.T283I | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.057); catalogued as COSV63581164; called by muse, mutect2, varscan2
- RSF1 | c.2630A>T p.E877V | Missense Mutation (SNP) | VAF 96/360 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as COSV100407243; called by muse, mutect2, varscan2
- RXRA | c.233C>T p.S78L | Missense Mutation (SNP) | VAF 68/192 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.08); catalogued as rs568762857, COSV62684269; called by muse, mutect2, varscan2
- RYR1 | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs769387053, COSV62097468; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR2 | c.6248C>T p.A2083V | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.057); catalogued as COSV63659491, COSV63686039, COSV63719384; called by muse, mutect2, varscan2
- RYR2 | c.6472C>T p.H2158Y | Missense Mutation (SNP) | VAF 36/162 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100770371; called by muse, varscan2
- RYR3 | c.1225C>T p.R409W | Missense Mutation (SNP) | VAF 52/174 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1450007550, COSV66789657; called by muse, mutect2, varscan2
- SACS | c.6084A>T p.E2028D | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs149018756; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SALL4 | c.1858A>G p.T620A | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as COSV53852287; called by muse, mutect2, varscan2
- SART3 | c.1060G>A p.A354T (on ENST00000228284; = p.A336T on NM_014706.4) | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.867); catalogued as rs749640007, COSV57207415; called by mutect2, varscan2
- SBF1 | c.3880G>A p.A1294T | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0.08); catalogued as COSV62367564; called by muse, mutect2, varscan2
- SCAF4 | c.749del p.P250Hfs*96 | Frame Shift Del (DEL) | VAF 78/308 reads (25%) | catalogued as COSV54589079; called by pindel, varscan2
- SCAMP1 | c.233A>C p.K78T | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV100210484; called by muse, mutect2, varscan2
- SCFD2 | c.893C>A p.P298H | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1177338682, COSV66371601; called by muse, varscan2
- SCN10A | c.1600C>T p.R534W | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as rs542554745, COSV71860392; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN3A | c.3032T>C p.M1011T | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as rs1390389488, COSV51810082; called by mutect2, varscan2
- SCN8A | c.5701G>A p.V1901I | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated (0.81); PolyPhen benign (0.014); catalogued as COSV61981690; called by muse, mutect2
- SCN9A | c.4021A>C p.N1341H (on ENST00000303354; = p.N1330H on NM_002977.3) | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs777811075, COSV57610218; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCUBE3 | c.821C>T p.T274M | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1264701581, COSV51460994; called by muse, mutect2, varscan2
- SDK1 | c.3538G>A p.V1180I | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs757729076, COSV67357657; called by muse, mutect2, varscan2
- SDR16C5 | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.021); catalogued as rs371326324, COSV58127271, COSV58128559; called by muse, mutect2, varscan2
- SDSL | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.076); catalogued as rs1224500174, COSV100615249; called by muse, varscan2
- SEC14L1 | c.1777C>T p.Q593* | Nonsense Mutation (SNP) | VAF 13/69 reads (19%) | catalogued as COSV66722307; called by muse, mutect2, varscan2
- SELE | c.1123C>T p.R375* | Nonsense Mutation (SNP) | VAF 11/36 reads (31%) | catalogued as rs759220052, COSV60975477; called by muse, mutect2, varscan2
- SEMA6A | c.2637del p.V881Ffs*20 | Frame Shift Del (DEL) | VAF 35/123 reads (28%) | catalogued as rs749631581, COSV56712590; called by mutect2, pindel, varscan2
- SEMA6B | c.107T>C p.V36A | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.108); catalogued as COSV100014860; called by muse, mutect2, varscan2
- SEMG2 | c.628A>T p.T210S | Missense Mutation (SNP) | VAF 26/233 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs1362709008, COSV65647488; called by muse, mutect2, varscan2
- SERPINE1 | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs774647903, COSV99776719; called by muse, mutect2, varscan2
- SETD1A | c.3350G>T p.R1117M | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.076); catalogued as COSV52687741; called by muse, mutect2, varscan2
- SETD1A | c.3688C>T p.R1230W | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as rs775225592, COSV52687751; called by muse, mutect2, varscan2
- SETD2 | c.7379C>T p.A2460V | Missense Mutation (SNP) | VAF 28/207 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV100339027; called by muse, mutect2, varscan2
712 further variants in this file (364 protein-altering or splice-affecting, 321 silent, 27 other) are not listed here.
